Somatic mutation profile of tumor specimen TCGA-F4-6570-01A (aliquot TCGA-F4-6570-01A-11D-1771-10) from TCGA case TCGA-F4-6570, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 78.8 years (28,772 days).
Specimen TCGA-F4-6570-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 32e66651-4cbb-49b0-b421-cb723c9889fb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-F4-6570-10A (Blood Derived Normal), aliquot TCGA-F4-6570-10A-01D-1771-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/02895b6a-cc59-442c-809f-19eea0696532

The open-access MAF lists 1,972 somatic variants for this specimen: 1,531 protein-altering or splice-affecting, 400 silent, 41 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,077, Silent 400, Frame Shift Del 275, Nonsense Mutation 59, Frame Shift Ins 57, Splice Site 30, Intron 19, Splice Region 17, In Frame Del 15, RNA 10, 3'UTR 7, 3'Flank 2.

Variants (750 of 1,972; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALPK3 | c.1417del p.Q473Sfs*30 | Frame Shift Del (DEL) | VAF 8/40 reads (20%) | catalogued as rs769139957; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- ARID1A | c.5164C>T p.R1722* | Nonsense Mutation (SNP) | VAF 74/243 reads (30%) | hotspot (GDC flag); catalogued as rs1485978447, COSV61371609; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BBS12 | c.1063C>T p.R355* | Nonsense Mutation (SNP) | VAF 11/62 reads (18%) | catalogued as rs121918327, CM070035, COSV58561593; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BMPR2 | c.994C>T p.R332* | Nonsense Mutation (SNP) | VAF 21/120 reads (18%) | catalogued as rs137852751, CM010163, COSV65808047; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- COL17A1 | c.3908G>A p.R1303Q | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.143); catalogued as rs121912771, CM970345; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL18A1 | c.3918dup p.G1307Rfs*9 (on ENST00000359759 / NM_130444.3; = p.G1072Rfs*9 on NM_030582.4) | Frame Shift Ins (INS) | VAF 10/18 reads (56%) | catalogued as rs749009747; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ERI1 | c.627del p.V210* | Frame Shift Del (DEL) | VAF 26/106 reads (25%) | catalogued as rs1563322318; ClinVar: likely pathogenic; called by pindel, varscan2
- ESCO2 | c.760del p.T254Lfs*13 | Frame Shift Del (DEL) | VAF 19/74 reads (26%) | catalogued as rs80359852; ClinVar: pathogenic; called by mutect2, varscan2
- FLNA | c.4599-1G>A p.X1533_splice | Splice Site (SNP) | VAF 9/125 reads (7%) | catalogued as rs1057518223, COSV100775425; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- IQSEC2 | c.848del p.G283Afs*23 (on ENST00000642864 / NM_001111125.3; = p.G78Afs*23 on NM_015075.2) | Frame Shift Del (DEL) | VAF 4/22 reads (18%) | catalogued as rs782660318, COSV64726734; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KCNB1 | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057518621, COSV65565954; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KCNJ10 | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs387906834, CM116767, COSV63633096; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYH11 | c.5787-4707del | Intron (DEL) | VAF 22/68 reads (32%) | catalogued as rs747392139, COSV100257523; ClinVar: uncertain significance / benign / likely benign / likely pathogenic; called by mutect2, varscan2
- PCDH19 | c.1091del p.P364Rfs*4 | Frame Shift Del (DEL) | VAF 17/44 reads (39%) | catalogued as rs758946412, CD134966; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PTPRS | c.4474C>T p.R1492W | Missense Mutation (SNP) | VAF 18/51 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs369295620; called by muse, mutect2, varscan2
- RUNX2 | c.90del p.S31Pfs*9 | Frame Shift Del (DEL) | VAF 14/75 reads (19%) | catalogued as rs397515538; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- WRN | c.3382del p.S1128Vfs*34 | Frame Shift Del (DEL) | VAF 34/114 reads (30%) | catalogued as rs778872619; ClinVar: pathogenic; called by pindel, varscan2
- ABCA1 | c.1596C>A p.F532L | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.488); catalogued as COSV66064495; called by muse, mutect2, varscan2
- ABCA12 | c.464del p.F155Sfs*17 | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | catalogued as rs1559168251; called by mutect2, pindel, varscan2
- ABCA13 | c.8626T>C p.F2876L | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as COSV101447286; called by muse, mutect2, varscan2
- ABCA5 | c.1283G>A p.R428Q | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.313); catalogued as rs149261056, COSV67018253; called by muse, mutect2, varscan2
- ABCC10 | c.2377G>A p.A793T (on ENST00000372530 / NM_001198934.2; = p.A765T on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as rs149179351; called by muse, mutect2, varscan2
- ABCC11 | c.3699-1G>T p.X1233_splice | Splice Site (SNP) | VAF 26/83 reads (31%) | catalogued as COSV62321799; called by muse, mutect2, varscan2
- ABCC11 | c.1033G>A p.V345I | Missense Mutation (SNP) | VAF 41/142 reads (29%) | SIFT tolerated (0.73); PolyPhen benign (0.134); catalogued as COSV62321804; called by muse, mutect2, varscan2
- ABCD4 | c.1322C>T p.T441I | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as rs905092359, COSV53991287; called by muse, mutect2, varscan2
- ABHD1 | c.503G>A p.R168Q | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs755869363, COSV99574546, COSV99574912; called by muse, mutect2, varscan2
- ABI2 | c.596G>A p.R199H (on ENST00000295851 / NM_001375719.1; = p.R193H on NM_005759.7 and 35 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.847); catalogued as rs1402325484, COSV99652368; called by muse, mutect2, varscan2
- ABI3BP | c.581T>C p.V194A | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52530771; called by muse, mutect2, varscan2
- AC231657.3 | c.692C>T p.A231V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as COSV59877414; called by muse, mutect2
- ACACA | c.4603C>T p.R1535W | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1019398644; called by muse, mutect2, varscan2
- ACACB | c.2594G>A p.S865N | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58130237; called by muse, mutect2, varscan2
- ACAD8 | c.210G>T p.K70N | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.085); catalogued as COSV55539471; called by muse, mutect2, varscan2
- ACD | c.1217G>A p.C406Y (on ENST00000620338; = p.C317Y on NM_022914.3) | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.867); catalogued as rs780639186, COSV54666431; called by muse, mutect2, varscan2
- ACO1 | c.2059G>A p.A687T | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV59377791; called by muse, mutect2, varscan2
- ACO1 | c.2489C>T p.T830I | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV59377804; called by muse, mutect2, varscan2
- ACOX1 | c.913G>A p.A305T | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs1166143285, COSV53131797; called by muse, mutect2, varscan2
- ACTBL2 | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.251); catalogued as rs772855283, COSV70661077; called by muse, mutect2, varscan2
- ADAM19 | c.2097T>C p.S699= | Splice Region (SNP) | VAF 19/78 reads (24%) | catalogued as COSV99978854; called by muse, varscan2
- ADAMTS15 | c.1322G>T p.S441I | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.656); catalogued as COSV54503850; called by muse, mutect2, varscan2
- ADAMTS2 | c.2210-2del p.X737_splice | Splice Site (DEL) | VAF 18/69 reads (26%) | catalogued as rs1219329381; called by mutect2, pindel, varscan2
- ADAMTSL3 | c.3227A>C p.K1076T | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.261); catalogued as COSV99076511; called by muse, mutect2
- ADAP2 | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.25); catalogued as COSV100437398; called by muse, mutect2, varscan2
- ADARB1 | c.1358A>T p.D453V | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62342710; called by muse, mutect2, varscan2
- ADD1 | c.2153del p.K718Rfs*11 | Frame Shift Del (DEL) | VAF 10/47 reads (21%) | catalogued as rs746468920; called by mutect2, pindel, varscan2
- ADGRA2 | c.2837C>T p.A946V | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.936); catalogued as COSV55102977; called by muse, mutect2, varscan2
- ADGRG2 | c.2366C>T p.T789M (on ENST00000379869 / NM_001079858.3; = p.T786M on NM_005756.4) | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs780666105, COSV61338004; called by muse, mutect2, varscan2
- ADGRG5 | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 51/182 reads (28%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.559); catalogued as rs974313487, COSV61082775; called by muse, mutect2, varscan2
- ADGRV1 | c.6050C>T p.T2017I | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV67980388; called by muse, mutect2, varscan2
- ADORA3 | c.836C>A p.P279H | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53985270, COSV53986619; called by muse, mutect2, varscan2
- AEBP2 | c.1049C>A p.P350H | Missense Mutation (SNP) | VAF 50/190 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as COSV56862314, COSV56862353; called by muse, mutect2, varscan2
- AFDN | c.3872G>A p.R1291Q | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.01); catalogued as rs759864399, COSV60039908; called by muse, mutect2, varscan2
- AGTPBP1 | c.587T>C p.L196S | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61269471; called by muse, mutect2, varscan2
- AHCTF1 | c.3778C>T p.R1260* (on ENST00000366508; = p.R1234* on NM_015446.5) | Nonsense Mutation (SNP) | VAF 62/235 reads (26%) | catalogued as rs1558223606, COSV58247045; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AHCTF1 | c.208C>T p.R70C (on ENST00000366508; = p.R44C on NM_015446.5) | Missense Mutation (SNP) | VAF 65/272 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.042); catalogued as rs1307075702, COSV58253990; called by muse, varscan2
- AICDA | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.473); catalogued as COSV57563693; called by muse, mutect2, varscan2
- AJUBA | c.1438G>A p.V480M | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as rs1024077752, COSV52984705; called by muse, mutect2, varscan2
- AKAP6 | c.5698G>C p.E1900Q | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV99805464; called by muse, mutect2, varscan2
- AKAP9 | c.116del p.K39Rfs*17 | Frame Shift Del (DEL) | VAF 22/56 reads (39%) | catalogued as COSV62339755; called by mutect2, varscan2
- AKAP9 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 16/177 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1233431465, COSV62341108; called by muse, mutect2
- AL121899.2 | c.595C>T p.Q199* | Nonsense Mutation (SNP) | VAF 13/73 reads (18%) | catalogued as COSV67349993, COSV67351847; called by muse, mutect2, varscan2
- ALDH16A1 | c.493C>T p.P165S | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV53193065; called by muse, mutect2, varscan2
- ALDH1L2 | c.2290T>A p.S764T | Missense Mutation (SNP) | VAF 30/172 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.292); catalogued as COSV51554103; called by muse, mutect2, varscan2
- ALOXE3 | c.254G>A p.S85N | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.8); PolyPhen benign (0.147); catalogued as COSV58554543; called by muse, mutect2, varscan2
- ALS2 | c.4875G>T p.E1625D | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.888); catalogued as COSV51885108; called by muse, mutect2, varscan2
- AMER1 | c.473A>C p.K158T | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as COSV57663072; called by muse, mutect2
- AMIGO3 | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); catalogued as COSV57537842; called by muse, mutect2, varscan2
- ANK2 | c.5827G>A p.G1943R | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.506); catalogued as rs367592943; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKRD11 | c.3931C>T p.R1311* | Nonsense Mutation (SNP) | VAF 11/94 reads (12%) | catalogued as COSV56355766; called by muse, mutect2, varscan2
- ANKRD28 | c.1831G>A p.V611I | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.081); catalogued as COSV67517259; called by muse, mutect2
- ANKRD33 | c.230G>A p.R77H (on ENST00000340970 / NM_001304459.2; = p.R212H on NM_182608.4) | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as rs751233923, COSV56604835; called by muse, varscan2
- ANKRD6 | c.2016del p.F672Lfs*34 (on ENST00000339746 / NM_001242809.2; = p.F667Lfs*34 on NM_014942.4) | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | catalogued as rs751514998, COSV100329734; called by pindel, varscan2
- ANO2 | c.820C>T p.R274C (on ENST00000356134 / NM_001278597.3; = p.R278C on NM_001278596.3) | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769882345, COSV59011923, COSV59026470; called by muse, mutect2, varscan2
- ANO3 | c.2664A>C p.R888S | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99886648; called by muse, mutect2
- AOAH | c.965G>A p.R322H | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as rs375296715; called by muse, mutect2, varscan2
- AP1S1 | c.361G>A p.G121R | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99973267; called by muse, mutect2
- AQP8 | c.363del p.M122Cfs*10 | Frame Shift Del (DEL) | VAF 9/66 reads (14%) | catalogued as rs759782104; called by mutect2, pindel, varscan2
- ARFGEF3 | c.1064del p.P355Hfs*11 | Frame Shift Del (DEL) | VAF 9/27 reads (33%) | catalogued as rs147530147; called by mutect2, pindel, varscan2
- ARFGEF3 | c.6119C>T p.A2040V | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs764438236, COSV52452082; called by mutect2, varscan2
- ARHGAP17 | c.2440del p.Q814Nfs*23 (on ENST00000289968 / NM_001006634.3; = p.Q736Nfs*23 on NM_018054.6) | Frame Shift Del (DEL) | VAF 21/149 reads (14%) | catalogued as rs773922861; called by mutect2, varscan2
- ARHGAP44 | c.447G>T p.M149I | Missense Mutation (SNP) | VAF 72/227 reads (32%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.856); catalogued as COSV99311765; called by muse, mutect2, varscan2
- ARHGDIB | c.503C>T p.A168V | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.442); catalogued as rs369111462; called by mutect2, varscan2
- ARHGEF1 | c.1084C>T p.P362S | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as rs781864535, COSV61526641; called by muse, mutect2, varscan2
- ARID2 | c.1331-1G>A p.X444_splice | Splice Site (SNP) | VAF 20/56 reads (36%) | catalogued as COSV57598791, COSV57613129; called by muse, mutect2, varscan2
- ARID2 | c.2864C>T p.P955L | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.165); catalogued as COSV57598801, COSV57610251; called by muse, mutect2, varscan2
- ARID4A | c.3295A>G p.K1099E | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100794681; called by muse, mutect2, varscan2
- ARL6 | c.280A>G p.I94V | Missense Mutation (SNP) | VAF 26/213 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0.013); catalogued as COSV100256639; called by muse, mutect2
- ARMCX1 | c.460C>T p.P154S | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV65704973; called by muse, mutect2, varscan2
- ARR3 | c.1108C>T p.R370W | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as rs901050347, COSV52103427; called by muse, mutect2, varscan2
- ASAP2 | c.2986T>A p.F996I | Missense Mutation (SNP) | VAF 17/176 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV53005567; called by muse, mutect2
- ASAP2 | c.2988C>A p.F996L | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV99432242; called by muse, varscan2
- ASL | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.059); catalogued as rs758359461, COSV100509027; called by muse, mutect2, varscan2
- ASMTL | c.732del p.G245Afs*47 | Frame Shift Del (DEL) | VAF 12/23 reads (52%) | catalogued as rs1438753766, COSV67243140; called by mutect2, varscan2
- ASPN | c.96G>T p.K32N | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.024); catalogued as COSV65015962; called by muse, varscan2
- ASPRV1 | c.582G>T p.K194N | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV57227574; called by muse, mutect2, varscan2
- ATAD2B | c.1404del p.F468Lfs*9 | Frame Shift Del (DEL) | VAF 46/180 reads (26%) | catalogued as rs866490133; called by mutect2, pindel, varscan2
- ATG2A | c.5581-1G>T p.X1861_splice | Splice Site (SNP) | VAF 12/60 reads (20%) | catalogued as COSV63475529; called by muse, varscan2
- ATMIN | c.662G>T p.R221M | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55145453, COSV55145477; called by muse, mutect2, varscan2
- ATN1 | c.3220G>A p.A1074T | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.815); catalogued as COSV57546494; called by muse, mutect2, varscan2
- ATP13A5 | c.1213C>A p.L405M | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV60866962, COSV60869429; called by muse, mutect2, varscan2
- ATP4A | c.1528C>T p.R510W | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as rs1437074011, COSV52866515; called by muse, mutect2, varscan2
- ATP5F1A | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 47/148 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.859); catalogued as COSV56359745; called by muse, mutect2, varscan2
- ATP5MC2 | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.16); catalogued as COSV58601065; called by muse, mutect2, varscan2
- ATP6V1H | c.928A>G p.I310V | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.169); catalogued as COSV62217386; called by muse, mutect2, varscan2
- ATP8B2 | c.536C>T p.A179V (on ENST00000672630; = p.A146V on NM_001005855.2) | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.244); catalogued as rs776939812, COSV59245184; called by muse, mutect2, varscan2
- ATRAID | c.746G>A p.R249H (on ENST00000611786; = p.R136H on NM_016085.5) | Missense Mutation (SNP) | VAF 83/241 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375386400; called by muse, mutect2, varscan2
- ATRX | c.5995C>T p.P1999S | Missense Mutation (SNP) | VAF 65/208 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.278); catalogued as COSV64873113; called by muse, mutect2, varscan2
- BAHD1 | c.1222G>A p.A408T | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV69083706, COSV69084416; called by muse, mutect2, varscan2
- BAIAP2L1 | c.1307del p.P436Hfs*60 | Frame Shift Del (DEL) | VAF 12/34 reads (35%) | catalogued as rs1405664842, COSV50055281; called by mutect2, pindel, varscan2
- BAIAP2L1 | c.858del p.A287Lfs*11 | Frame Shift Del (DEL) | VAF 30/120 reads (25%) | catalogued as COSV50058748; called by mutect2, pindel, varscan2
- BAZ1B | c.1085C>A p.P362H | Missense Mutation (SNP) | VAF 53/172 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV59989470, COSV59994618; called by muse, mutect2, varscan2
- BCLAF3 | c.1575T>A p.D525E | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61413371; called by muse, mutect2, varscan2
- BEST4 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.055); catalogued as rs933903611, COSV64733607; called by muse, mutect2, varscan2
- BEX2 | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 43/164 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as rs199515438, COSV65500709; called by muse, mutect2, varscan2
- BHMT | c.101A>T p.E34V | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57153776; called by muse, mutect2, varscan2
- BICRA | c.2810del p.P937Hfs*10 | Frame Shift Del (DEL) | VAF 11/48 reads (23%) | catalogued as rs755506199; called by mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 38/73 reads (52%) | catalogued as rs772920507, COSV65808737; called by mutect2, pindel, varscan2
- BPHL | c.131T>C p.V44A | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as COSV66743162; called by muse, mutect2
- BRCC3 | c.179G>A p.R60H | Missense Mutation (SNP) | VAF 42/279 reads (15%) | SIFT tolerated, low confidence (0.59); PolyPhen possibly damaging (0.684); catalogued as rs781808889, COSV57462003; called by muse, varscan2
- BRINP2 | c.1442A>C p.N481T | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as COSV100838304, COSV64176218; called by muse, mutect2, varscan2
- BRIP1 | c.3178G>A p.V1060I | Missense Mutation (SNP) | VAF 47/153 reads (31%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.012); catalogued as rs149016505; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRPF1 | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1465578133, COSV57403643; called by muse, varscan2
- BRWD1 | c.4057A>G p.I1353V | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as rs1195211839, COSV60893639; called by muse, mutect2, varscan2
- BRWD3 | c.1162G>A p.A388T | Missense Mutation (SNP) | VAF 136/486 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64745141; called by muse, mutect2, varscan2
- BSG | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.074); catalogued as rs780701101, COSV100345121; called by muse, mutect2, varscan2
- BSN | c.3316A>G p.T1106A | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56514285; called by muse, mutect2, varscan2
- BUB1B | c.2351C>T p.A784V | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs142705245; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C16orf70 | c.1226C>T p.P409L | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.037); catalogued as COSV54627469; called by muse, mutect2, varscan2
- C1RL | c.24del p.K9Nfs*44 | Frame Shift Del (DEL) | VAF 23/84 reads (27%) | catalogued as COSV56925742; called by mutect2, pindel, varscan2
- C1orf115 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.573); catalogued as rs774058620, COSV54273465; called by muse, mutect2, varscan2
- C1orf226 | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.116); catalogued as COSV63394726; called by muse, mutect2, varscan2
- C6orf118 | c.1138A>T p.I380L | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV57813458; called by muse, mutect2, varscan2
- C9orf40 | c.559G>A p.G187R | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.563); catalogued as rs1396800317, COSV65228402; called by muse, mutect2, varscan2
- CA12 | c.485A>G p.N162S | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV51604509; called by muse, mutect2, varscan2
- CACNA1A | c.3603dup p.E1202Rfs*18 | Frame Shift Ins (INS) | VAF 38/126 reads (30%) | catalogued as rs747879307; called by mutect2, varscan2
- CACNA1E | c.3324G>T p.E1108D | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0.101); catalogued as COSV62385264; called by muse, varscan2
- CACNA1G | c.2383C>A p.L795I | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.384); catalogued as COSV61721696; called by muse, mutect2, varscan2
- CACNA1G | c.6493C>T p.R2165W | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.394); catalogued as rs771907755, COSV61721716; called by muse, mutect2, varscan2
- CACNB4 | c.1262C>T p.T421M | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.65); catalogued as rs769896776, COSV52390554; called by muse, mutect2, varscan2
- CACTIN | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs777564935, COSV50273298; called by muse, mutect2, varscan2
- CADM4 | c.337C>A p.H113N | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.877); catalogued as COSV99731749; called by muse, mutect2, varscan2
- CALCOCO1 | c.89T>C p.V30A | Missense Mutation (SNP) | VAF 50/164 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50412278; called by muse, mutect2, varscan2
- CAMK2D | c.1365G>T p.W455C | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV56426235, COSV56427373; called by muse, mutect2, varscan2
- CAMTA1 | c.4002G>T p.Q1334H | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.556); catalogued as COSV57886741; called by muse, mutect2, varscan2
- CAPN10 | c.1027C>T p.P343S | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.021); catalogued as COSV99550652; called by muse, mutect2, varscan2
- CAPN12 | c.1225del p.A409Lfs*30 | Frame Shift Del (DEL) | VAF 5/18 reads (28%) | catalogued as rs1341489183; called by mutect2, pindel, varscan2
- CAPN5 | c.1375G>T p.G459C (on ENST00000456580; = p.G419C on NM_004055.5) | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV53686199; called by muse, mutect2, varscan2
- CAPNS1 | c.292G>A p.V98I | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as COSV55822423, COSV55823124; called by muse, mutect2, varscan2
- CARS2 | c.1609G>T p.G537C | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57284710; called by muse, mutect2, varscan2
- CASP8AP2 | c.5723C>T p.A1908V | Missense Mutation (SNP) | VAF 21/184 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV52745764; called by muse, mutect2, varscan2
- CASZ1 | c.3263C>T p.P1088L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as rs538567404, COSV59732185; called by mutect2, varscan2
- CASZ1 | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs937250159, COSV59733106; called by muse, mutect2, varscan2
- CATSPERD | c.1645G>A p.D549N | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.808); catalogued as rs191427801; called by muse, mutect2, varscan2
- CBLL1 | c.710A>G p.H237R | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.978); catalogued as COSV99756051; called by mutect2, varscan2
- CBX8 | c.949G>A p.G317R | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.67); PolyPhen benign (0.039); catalogued as COSV53935701, COSV53935734; called by muse, mutect2, varscan2
- CCDC110 | c.1624G>A p.A542T | Missense Mutation (SNP) | VAF 25/175 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs772802973, COSV56869806; called by muse, mutect2, varscan2
- CCDC136 | c.1970T>C p.V657A | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as COSV52797236; called by muse, mutect2, varscan2
- CCDC14 | c.1145del p.N382Mfs*2 (on ENST00000488653; = p.N334Mfs*2 on NM_022757.5) | Frame Shift Del (DEL) | VAF 25/90 reads (28%) | catalogued as rs1559796959; called by mutect2, pindel, varscan2
- CCDC142 | c.1023A>T p.A341= | Splice Region (SNP) | VAF 7/66 reads (11%) | catalogued as COSV51776550; called by muse, varscan2
- CCDC144A | c.179G>A p.S60N | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.213); catalogued as rs773397079, COSV61402789; called by muse, mutect2, varscan2
- CCDC149 | c.953G>T p.R318M | Missense Mutation (SNP) | VAF 53/220 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60877558; called by muse, mutect2, varscan2
- CCDC150 | c.175del p.R59Efs*10 | Frame Shift Del (DEL) | VAF 9/38 reads (24%) | catalogued as rs34248242; called by mutect2, pindel, varscan2
- CCDC62 | c.861G>A p.Q287= | Splice Region (SNP) | VAF 7/25 reads (28%) | catalogued as COSV53431295, COSV99457843; called by muse, mutect2, varscan2
- CCDC66 | c.1613G>A p.R538Q (on ENST00000394672 / NM_001353147.1; = p.R504Q on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 101/298 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs774817360, COSV58302168; called by muse, mutect2, varscan2
- CCDC82 | c.971T>C p.L324S | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as COSV53592522, COSV53595637; called by muse, mutect2, varscan2
- CCDC88B | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs746169612, COSV57265286; called by muse, mutect2, varscan2
- CCDC96 | c.398C>T p.A133V | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.003); catalogued as rs1431815971, COSV59508289; called by muse, mutect2, varscan2
- CCNB1 | c.371C>G p.T124S | Missense Mutation (SNP) | VAF 40/160 reads (25%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV56509312; called by muse, mutect2, varscan2
- CCNF | c.1918G>A p.V640M | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); catalogued as rs373872375; called by muse, mutect2, varscan2
- CCNQ | c.364G>A p.V122M | Missense Mutation (SNP) | VAF 40/167 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1557026564, COSV52344153; called by muse, mutect2, varscan2
- CCT8L2 | c.149G>A p.C50Y | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV63461850; called by muse, mutect2, varscan2
- CD1E | c.1082G>A p.R361K | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.071); catalogued as COSV63770348; called by muse, mutect2, varscan2
- CD44 | c.797-1G>C p.X266_splice | Splice Site (SNP) | VAF 10/44 reads (23%) | catalogued as COSV99556101; called by muse, mutect2
- CD74 | c.726G>T p.Q242H | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50532246; called by muse, mutect2, varscan2
- CDH1 | c.1528G>A p.A510T | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55729310; called by muse, mutect2, varscan2
- CDH17 | c.1127T>G p.F376C | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.748); catalogued as COSV50326299; called by muse, mutect2
- CDH18 | c.1960A>T p.N654Y | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56908083; called by muse, mutect2, varscan2
- CDH18 | c.37del p.L13* | Frame Shift Del (DEL) | VAF 31/121 reads (26%) | catalogued as COSV99931228; called by mutect2, pindel, varscan2
- CDH2 | c.467G>T p.R156M | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52274189; called by muse, mutect2, varscan2
- CDH20 | c.1048A>G p.T350A | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.079); catalogued as COSV53006222; called by muse, mutect2, varscan2
- CDH4 | c.1433C>T p.A478V | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT tolerated (0.88); PolyPhen possibly damaging (0.881); catalogued as rs763582219, COSV64644937; called by muse, mutect2, varscan2
- CDH7 | c.1490G>T p.G497V | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV59882917, COSV59887056; called by muse, mutect2, varscan2
- CDH8 | c.202A>T p.M68L | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV54854122; called by muse, mutect2, varscan2
- CDHR1 | c.641A>G p.D214G | Missense Mutation (SNP) | VAF 73/216 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60560378; called by muse, mutect2, varscan2
- CDHR1 | c.1211G>A p.G404D | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.132); catalogued as rs752039450, COSV60560402; called by muse, mutect2, varscan2
- CDK5R1 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as COSV55577716, COSV55581856; called by muse, mutect2, varscan2
- CDKL5 | c.3052C>T p.L1018F | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV66106012; called by muse, mutect2, varscan2
- CDKN2AIP | c.1546T>G p.C516G | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); catalogued as COSV56626864; called by muse, mutect2, varscan2
- CDRT1 | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 19/229 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs570653295, COSV99887425; called by muse, mutect2, varscan2
- CDYL | c.1142C>T p.T381M (on ENST00000328908 / NM_001368125.1; = p.T327M on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs148330526; called by muse, varscan2
- CDYL | c.1460C>T p.T487I (on ENST00000328908 / NM_001368125.1; = p.T433I on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.405); catalogued as COSV100190432; called by muse, mutect2, varscan2
- CEACAM6 | c.808T>A p.S270T | Missense Mutation (SNP) | VAF 48/165 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.936); catalogued as COSV52266826; called by muse, mutect2, varscan2
- CEL | c.343A>G p.K115E (on ENST00000673714; = p.K112E on NM_001807.6) | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.203); catalogued as COSV60826485; called by muse, mutect2, varscan2
- CEMIP | c.540del p.F180Lfs*44 | Frame Shift Del (DEL) | VAF 28/109 reads (26%) | catalogued as rs753314096; called by mutect2, pindel, varscan2
- CENPC | c.616del p.R206Gfs*2 | Frame Shift Del (DEL) | VAF 71/261 reads (27%) | catalogued as rs1325731082; called by mutect2, pindel, varscan2
- CENPE | c.7993A>G p.S2665G | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs758197733, COSV99479565; called by mutect2, varscan2
- CENPJ | c.2825+2T>G p.X942_splice | Splice Site (SNP) | VAF 16/148 reads (11%) | catalogued as COSV101121596; called by muse, mutect2
- CEP128 | c.481C>T p.L161F | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as COSV53673191; called by muse, mutect2, varscan2
- CEP135 | c.815A>G p.H272R | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.206); catalogued as COSV57258639; called by muse, mutect2, varscan2
- CEP135 | c.1730A>G p.D577G | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.552); catalogued as COSV57258649; called by muse, varscan2
- CERKL | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as COSV100183816, COSV100184315; called by muse, mutect2, varscan2
- CFAP43 | c.2858A>G p.Q953R | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV99531137; called by muse, mutect2
- CFAP61 | c.575A>G p.D192G | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55643796; called by muse, varscan2
- CFHR2 | c.220G>C p.E74Q | Missense Mutation (SNP) | VAF 26/160 reads (16%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.991); catalogued as COSV66380688; called by muse, mutect2, varscan2
- CGN | c.313T>C p.Y105H | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.857); catalogued as COSV99643046; called by muse, mutect2, varscan2
- CHAD | c.423del p.L142Cfs*42 | Frame Shift Del (DEL) | VAF 19/78 reads (24%) | catalogued as COSV51971952; called by mutect2, pindel, varscan2
- CHD1L | c.1385+3_1385+6del p.X462_splice | Splice Site (DEL) | VAF 10/76 reads (13%) | catalogued as rs782135795; called by pindel, varscan2
- CHD4 | c.4354C>T p.R1452W (on ENST00000357008 / NM_001363606.2; = p.R1465W on NM_001273.5) | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1321427698, COSV58896314; called by muse, mutect2, varscan2
- CHD6 | c.4211T>A p.V1404D | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV100951408; called by muse, mutect2, varscan2
- CHD6 | c.1995G>T p.E665D | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.649); catalogued as COSV100498813; called by muse, mutect2, varscan2
- CHD8 | c.5875G>A p.A1959T (on ENST00000646647 / NM_001170629.2; = p.A1680T on NM_020920.4) | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.48); PolyPhen benign (0.017); catalogued as COSV100765274, COSV63036543; called by muse, mutect2, varscan2
- CHD8 | c.4429C>T p.R1477* (on ENST00000646647 / NM_001170629.2; = p.R1198* on NM_020920.4) | Nonsense Mutation (SNP) | VAF 10/42 reads (24%) | catalogued as rs1555314390, COSV63218852; called by muse, mutect2, varscan2
- CHERP | c.2188_2190del p.E730del | In Frame Del (DEL) | VAF 9/51 reads (18%) | catalogued as rs1366906373; called by mutect2, pindel, varscan2
- CHGB | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.354); catalogued as rs369985726; called by muse, mutect2, varscan2
- CHKB | c.941G>A p.R314H | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as rs577953900, COSV56415464; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHRM3 | c.904C>T p.R302C | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as rs200967479, COSV55083513; called by muse, mutect2, varscan2
- CHRM4 | c.1084G>A p.A362T | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.028); catalogued as COSV100642168; called by muse, varscan2
- CHRNB1 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.91); catalogued as COSV53439163; called by muse, mutect2, varscan2
- CHSY1 | c.673G>A p.V225M | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.87); PolyPhen benign (0.088); catalogued as rs748806147, COSV54251818; called by muse, mutect2, varscan2
- CLASP2 | c.3576T>A p.D1192E (on ENST00000359576; = p.D1191E on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 65/182 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV56277982; called by muse, mutect2, varscan2
- CLCN3 | c.706G>T p.A236S | Missense Mutation (SNP) | VAF 85/281 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV100641863; called by muse, mutect2, varscan2
- CLDN10 | c.110T>C p.V37A | Missense Mutation (SNP) | VAF 83/169 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100971228; called by muse, mutect2, varscan2
- CLEC18C | c.308C>T p.T103I | Missense Mutation (SNP) | VAF 44/400 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.255); catalogued as COSV100032282; called by muse, mutect2
- CLIC2 | c.212C>T p.P71L | Missense Mutation (SNP) | VAF 53/150 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782270791, COSV58935841; called by muse, mutect2, varscan2
- CLIP1 | c.3250-1G>T p.X1084_splice (on ENST00000620786 / NM_001247997.1; = p.X1073_splice on NM_002956.2) | Splice Site (SNP) | VAF 68/197 reads (35%) | catalogued as COSV100212519; called by muse, mutect2, varscan2
- CLIP3 | c.63G>T p.E21D | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.184); catalogued as COSV53077784; called by muse, mutect2, varscan2
- CLPS | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as rs529464575, COSV52566001; called by muse, mutect2, varscan2
- CLSTN1 | c.2566G>A p.V856I (on ENST00000377298 / NM_001009566.3; = p.V846I on NM_014944.4) | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.987); catalogued as rs751722195, COSV63127537; called by muse, mutect2, varscan2
- CMPK2 | c.1134T>A p.S378R | Missense Mutation (SNP) | VAF 26/151 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.643); catalogued as COSV99879144; called by muse, mutect2, varscan2
- CMTR2 | c.1254G>A p.W418* | Nonsense Mutation (SNP) | VAF 26/90 reads (29%) | catalogued as COSV57602808; called by muse, varscan2
- CNNM1 | c.1133G>A p.R378H | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as COSV63200836; called by muse, mutect2, varscan2
- CNNM2 | c.1175C>T p.P392L | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV100881772; called by muse, mutect2, varscan2
- CNTN3 | c.2990T>C p.M997T | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV55165443; called by muse, varscan2
- CNTNAP2 | c.1172A>C p.N391T | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV62155003; called by muse, mutect2, varscan2
- CNTRL | c.6590_6592del p.E2197del | In Frame Del (DEL) | VAF 12/38 reads (32%) | catalogued as rs754427403; called by mutect2, pindel, varscan2
- COBL | c.2111G>A p.G704D | Missense Mutation (SNP) | VAF 85/267 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375788304; called by muse, mutect2, varscan2
- COG1 | c.461A>G p.H154R | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV55428646; called by muse, mutect2, varscan2
- COL12A1 | c.3553A>T p.I1185F | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV100486848; called by muse, mutect2, varscan2
- COL13A1 | c.391G>A p.G131R | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375057935, COSV100637505; called by muse, mutect2, varscan2
- COL14A1 | c.3215T>C p.V1072A | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.389); catalogued as COSV99921061; called by muse, mutect2
- COL26A1 | c.648del p.S218Lfs*131 (on ENST00000313669 / NM_001278563.3; = p.S216Lfs*131 on NM_133457.4) | Frame Shift Del (DEL) | VAF 7/67 reads (10%) | catalogued as rs762324149; called by mutect2, pindel
- COL2A1 | c.113G>T p.G38V | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.273); catalogued as COSV61528745; called by muse, mutect2, varscan2
- COL4A2 | c.1237G>A p.G413R | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1464563247, COSV64625507; called by muse, mutect2, varscan2
- COL5A1 | c.4613C>T p.P1538L | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs775335297, COSV65666450; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL7A1 | c.8536C>T p.P2846S | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (0.75); PolyPhen probably damaging (0.994); catalogued as rs750604521, COSV56476151; called by muse, mutect2, varscan2
- COL9A3 | c.1204C>T p.R402* | Nonsense Mutation (SNP) | VAF 13/34 reads (38%) | catalogued as rs989413835, COSV59651079, COSV59657531; called by muse, mutect2, varscan2
- COLQ | c.1007C>T p.A336V | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); catalogued as COSV101082231; called by muse, mutect2, varscan2
- COQ8B | c.767C>T p.A256V | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.455); catalogued as rs201827222, COSV54685871; called by muse, mutect2, varscan2
- CPA3 | c.965C>G p.P322R | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.78); catalogued as rs1191216293, COSV56044165; called by muse, mutect2, varscan2
- CPB2 | c.5A>C p.K2T | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51672801; called by muse, mutect2, varscan2
- CPEB4 | c.473T>C p.L158S | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0); catalogued as COSV99437933; called by muse, mutect2, varscan2
- CRAMP1 | c.3556A>G p.N1186D | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.05); catalogued as COSV51960408; called by muse, mutect2, varscan2
- CRAT | c.1804C>T p.R602C | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); catalogued as COSV100540204; called by muse, mutect2, varscan2
- CRLF2 | c.643C>T p.R215W | Missense Mutation (SNP) | VAF 123/416 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs759127718, COSV67493497; called by muse, mutect2, varscan2
- CRMP1 | c.1357G>A p.V453I | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.07); catalogued as rs768538875, COSV61478733; called by muse, mutect2, varscan2
- CRNKL1 | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 54/126 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs752211557, COSV55622354; called by muse, mutect2, varscan2
- CROCC | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs768236725, COSV65010703; called by muse, mutect2, varscan2
- CSF3R | c.2273G>T p.S758I | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs1373421904, COSV58964419; called by muse, mutect2, varscan2
- CSF3R | c.1404del p.S469Afs*22 | Frame Shift Del (DEL) | VAF 16/88 reads (18%) | catalogued as rs747437399; called by mutect2, pindel, varscan2
- CSK | c.956A>G p.N319S | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV54972929; called by muse, mutect2, varscan2
- CSMD1 | c.4903G>T p.G1635W (on ENST00000520002; = p.G1634W on NM_033225.6) | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59295043; called by muse, mutect2, varscan2
- CSNK1E | c.1102T>C p.S368P | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.333); catalogued as COSV100725129; called by muse, mutect2, varscan2
- CSNK1G1 | c.307C>T p.Q103* | Nonsense Mutation (SNP) | VAF 11/61 reads (18%) | catalogued as COSV57307491; called by muse, mutect2, varscan2
- CSNK2A2 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV52641297, COSV52642546; called by muse, mutect2, varscan2
- CSTF2 | c.1313G>A p.R438H | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.572); catalogued as rs767318301, COSV65893688; called by muse, mutect2, varscan2
- CTBP1 | c.148A>G p.T50A | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.288); catalogued as COSV52072404; called by muse, mutect2
- CTNNA1 | c.2393C>T p.A798V | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57070828, COSV57074679; called by muse, mutect2, varscan2
- CTNNA1 | c.2695G>A p.E899K | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV57070845; called by muse, mutect2, varscan2
- CTNNA3 | c.2246C>T p.A749V | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.247); catalogued as rs1211245436, COSV65522418; called by muse, mutect2, varscan2
- CTNNBL1 | c.172del p.R58Gfs*25 | Frame Shift Del (DEL) | VAF 5/25 reads (20%) | catalogued as rs761516328; called by mutect2, pindel, varscan2
- CTNND2 | c.1327del p.D443Tfs*113 | Frame Shift Del (DEL) | VAF 21/71 reads (30%) | catalogued as rs1271012872; called by mutect2, pindel, varscan2
- CTNND2 | c.83C>T p.T28M | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.23); catalogued as rs140086280; called by muse, mutect2, varscan2
- CTPS2 | c.1450-1G>A p.X484_splice | Splice Site (SNP) | VAF 12/62 reads (19%) | catalogued as COSV63721607; called by muse, varscan2
- CTSS | c.116A>G p.Y39C | Missense Mutation (SNP) | VAF 54/162 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64565998; called by muse, mutect2, varscan2
- CUBN | c.10423C>T p.P3475S | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV64710104; called by muse, mutect2, varscan2
- CUBN | c.2556A>T p.Q852H | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.878); catalogued as COSV64710110, COSV64721355, COSV64726238; called by muse, mutect2, varscan2
- CUL1 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as COSV57387385; called by muse, mutect2, varscan2
- CUX1 | c.3433G>A p.G1145S | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52893487; called by muse, mutect2, varscan2
- CX3CR1 | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.027); catalogued as rs748219184, COSV64193323; called by muse, mutect2, varscan2
- CXCR2 | c.959A>C p.K320T | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs1231014487, COSV100579207; called by muse, mutect2, varscan2
- CXorf65 | c.415G>T p.A139S | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.142); catalogued as COSV52147569; called by muse, mutect2, varscan2
- CXorf66 | c.179T>A p.V60D | Missense Mutation (SNP) | VAF 95/303 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV65168973; called by muse, mutect2, varscan2
- CYBB | c.623C>T p.T208I | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV66084960; called by muse, mutect2, varscan2
- CYLC1 | c.1271del p.K424Rfs*69 | Frame Shift Del (DEL) | VAF 7/34 reads (21%) | catalogued as rs1385226543; called by mutect2, varscan2
- DAAM1 | c.3121C>T p.R1041C | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62835533; called by muse, mutect2, varscan2
- DACH1 | c.674G>C p.G225A | Missense Mutation (SNP) | VAF 12/131 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV57492753; called by muse, mutect2
- DCAF12L2 | c.625G>A p.V209M | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63580738; called by muse, mutect2, varscan2
- DCAF4L2 | c.709C>T p.P237S | Missense Mutation (SNP) | VAF 39/168 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV60477198; called by muse, mutect2, varscan2
- DCC | c.3974A>T p.E1325V | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV101473672; called by muse, mutect2, varscan2
- DCHS1 | c.3722C>T p.A1241V | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as rs201076402, COSV55032199; called by muse, mutect2, varscan2
- DCT | c.247C>T p.R83C | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763411727, COSV65467933; called by muse, mutect2, varscan2
- DCX | c.890G>T p.S297I | Missense Mutation (SNP) | VAF 29/151 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); catalogued as COSV57566946, COSV57576014; called by muse, mutect2, varscan2
- DDX18 | c.1823A>G p.Q608R | Missense Mutation (SNP) | VAF 36/255 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs762177632, COSV54305721; called by muse, mutect2
- DDX54 | c.685C>T p.H229Y | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100014290; called by muse, mutect2, varscan2
- DENND2D | c.713G>A p.C238Y | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as COSV62958531; called by muse, mutect2, varscan2
- DEPDC5 | c.*700+2T>C | Splice Site (SNP) | VAF 26/77 reads (34%) | catalogued as COSV99836904; called by muse, mutect2, varscan2
- DGKZ | c.2938+2T>C p.X980_splice (on ENST00000454345 / NM_001105540.2; = p.X792_splice on NM_003646.4) | Splice Site (SNP) | VAF 15/49 reads (31%) | catalogued as COSV100552164; called by muse, mutect2, varscan2
- DHDH | c.518C>G p.A173G | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs543413361; called by mutect2, varscan2
- DHRS2 | c.776G>A p.C259Y | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51630898; called by muse, mutect2, varscan2
- DHRS9 | c.669del p.K223Nfs*25 | Frame Shift Del (DEL) | VAF 16/62 reads (26%) | catalogued as rs756920263; called by mutect2, varscan2
- DHX15 | c.767T>C p.V256A | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.588); catalogued as COSV61026040; called by muse, mutect2, varscan2
- DHX9 | c.2846C>T p.T949I | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.566); catalogued as COSV62358645; called by muse, mutect2, varscan2
- DIDO1 | c.3541+6C>T | Splice Region (SNP) | VAF 7/38 reads (18%) | catalogued as rs765548395, COSV56621287; called by muse, mutect2, varscan2
- DIP2B | c.882A>T p.E294D | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.163); catalogued as COSV56580363; called by muse, mutect2, varscan2
- DIP2C | c.1494+1G>A p.X498_splice | Splice Site (SNP) | VAF 27/87 reads (31%) | catalogued as COSV55150017; called by muse, mutect2, varscan2
- DIS3L2 | c.2114G>A p.R705H | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1265389937, COSV56050090, COSV56050164; called by muse, mutect2, varscan2
- DISP3 | c.2491G>A p.V831M | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs755361319, COSV53822553; called by muse, mutect2, varscan2
- DLC1 | c.4448T>C p.M1483T (on ENST00000276297 / NM_001348081.2; = p.M1046T on NM_006094.5) | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as COSV99366341; called by muse, mutect2, varscan2
- DLG2 | c.1351G>A p.A451T | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV54628441; called by muse, mutect2, varscan2
- DMRT2 | c.1305T>G p.N435K | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.19); catalogued as COSV52401172; called by muse, mutect2, varscan2
- DMXL2 | c.7474del p.S2492Qfs*21 | Frame Shift Del (DEL) | VAF 57/217 reads (26%) | catalogued as rs1307838825; called by mutect2, pindel, varscan2
- DNAH1 | c.3363T>A p.N1121K | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as COSV70227134; called by muse, mutect2, varscan2
- DNAH5 | c.8725C>T p.R2909C | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs369744828; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH7 | c.2478del p.V827* | Frame Shift Del (DEL) | VAF 34/120 reads (28%) | catalogued as rs752238407, COSV56751321; called by mutect2, pindel, varscan2
- DNAH7 | c.1100T>G p.L367R | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100413525, COSV56755783; called by muse, mutect2, varscan2
- DNAH8 | c.4376G>A p.G1459E | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV59431716; called by muse, mutect2, varscan2
- DNAJA4 | c.455C>T p.P152L (on ENST00000343789; = p.P181L on NM_018602.3) | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.022); catalogued as rs200635299; called by muse, mutect2, varscan2
- DNM2 | c.1643A>G p.E548G (on ENST00000355667 / NM_001005360.3; = p.E544G on NM_004945.3) | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV58958069; called by muse, mutect2, varscan2
- DOCK1 | c.514A>T p.N172Y | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54733065; called by muse, mutect2, varscan2
- DOCK10 | c.1402G>A p.D468N | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.085); catalogued as rs1412743921, COSV51358095; called by muse, mutect2, varscan2
- DOCK2 | c.3953T>C p.L1318P | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56947146; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 22/91 reads (24%) | catalogued as rs782552436; called by mutect2, varscan2
- DOCK8 | c.4109G>A p.R1370H | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); catalogued as rs753480025, COSV66618594; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DOCK9 | c.124C>A p.P42T | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV59622913; called by muse, mutect2, varscan2
- DOP1A | c.2138G>A p.R713Q | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.35); catalogued as rs749004130, COSV52707929; called by muse, mutect2, varscan2
- DOP1A | c.5594C>T p.S1865L | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52707942; called by muse, mutect2, varscan2
- DPCD | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs780393185, COSV64509075; called by muse, mutect2, varscan2
- DPRX | c.358G>A p.V120M | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV64949313; called by muse, mutect2, varscan2
- DPYSL3 | c.1453C>T p.R485W | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747491194, COSV58324930; called by muse, mutect2, varscan2
- DPYSL4 | c.1460G>T p.R487M | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV100063726; called by mutect2, varscan2
- DRC7 | c.856A>G p.M286V | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs770219988, COSV61053548; called by muse, mutect2, varscan2
- DRG2 | c.962G>A p.R321H | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.429); catalogued as rs552445784, COSV52753403; called by muse, mutect2, varscan2
- DSP | c.2027G>A p.R676H | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs777782794, COSV101131282; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DSPP | c.2477G>A p.S826N | Missense Mutation (SNP) | VAF 65/211 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.261); catalogued as COSV56808798; called by muse, mutect2, varscan2
- DUOX1 | c.257C>A p.P86H | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); catalogued as COSV99973634; called by muse, mutect2, varscan2
- DUOX1 | c.3208G>A p.A1070T | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.222); catalogued as rs370420245, COSV58478461; called by muse, mutect2, varscan2
- DXO | c.979T>C p.C327R | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770840590, COSV100514884; called by muse, mutect2
- DYNC2H1 | c.10387C>A p.Q3463K | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.67); PolyPhen benign (0.027); catalogued as COSV100520083, COSV62095220; called by muse, mutect2, varscan2
- DZANK1 | c.1346dup p.E450Gfs*16 (on ENST00000262547 / NM_001099407.1; = p.E257Gfs*16 on NM_018152.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 58/215 reads (27%) | catalogued as rs778923173; called by mutect2, pindel, varscan2
- ECT2 | c.2555G>A p.R852Q (on ENST00000392692 / NM_001349098.2; = p.R821Q on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1357254587, COSV99222083; called by muse, mutect2, varscan2
- EEA1 | c.2401A>C p.K801Q | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59283531; called by muse, mutect2, varscan2
- EEF1AKMT4 | c.628C>T p.L210F | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs1347010821, COSV56181617; called by muse, mutect2, varscan2
- EFCAB5 | c.450del p.K150Nfs*17 | Frame Shift Del (DEL) | VAF 22/66 reads (33%) | catalogued as rs760813779; called by mutect2, varscan2
- EFCAB5 | c.3746C>T p.T1249M | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.921); catalogued as rs781519608, COSV57927106; called by muse, mutect2, varscan2
- EFL1 | c.1703G>A p.G568E | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99186638; called by muse, mutect2, varscan2
- EFR3A | c.731G>A p.R244Q | Missense Mutation (SNP) | VAF 60/169 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.485); catalogued as rs778749379, COSV99603779; called by muse, mutect2, varscan2
- EIF2AK3 | c.3278G>A p.R1093H | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs765878566, COSV57545739; called by muse, mutect2, varscan2
- EIF2AK3 | c.377del p.K126Sfs*27 | Frame Shift Del (DEL) | VAF 18/68 reads (26%) | catalogued as COSV57545444; called by mutect2, pindel, varscan2
- EIF3B | c.2252G>A p.R751H | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as rs375864470; called by muse, mutect2, varscan2
- EIF3L | c.1009G>A p.A337T | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.8); PolyPhen benign (0.012); catalogued as rs1453440089, COSV101094675; called by muse, mutect2
- EIF4G1 | c.668C>T p.T223M (on ENST00000346169 / NM_198241.3; = p.T27M on NM_004953.5) | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as rs752416317, COSV59989715; called by muse, mutect2, varscan2
- ELAPOR1 | c.1546-2A>C p.X516_splice | Splice Site (SNP) | VAF 14/44 reads (32%) | catalogued as COSV64040104; called by muse, mutect2
- ELF1 | c.1025C>T p.T342I | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.33); catalogued as rs909031062, COSV53497659; called by muse, mutect2
- ELMO2 | c.940G>A p.D314N | Missense Mutation (SNP) | VAF 55/118 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as COSV51681789; called by muse, mutect2, varscan2
- EMC1 | c.2644C>T p.R882C | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778938462, COSV64345342; called by muse, mutect2, varscan2
- EMID1 | c.587-2A>G p.X196_splice | Splice Site (SNP) | VAF 15/31 reads (48%) | catalogued as COSV61828782; called by muse, varscan2
- ENPP1 | c.2543G>A p.C848Y | Missense Mutation (SNP) | VAF 58/204 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62930858; called by muse, mutect2, varscan2
- EPB41 | c.2120G>A p.R707H (on ENST00000343067 / NM_001166005.2; = p.R465H on NM_004437.4) | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1330436509, COSV58042372; called by muse, mutect2, varscan2
- EPB41L5 | c.794T>C p.L265S | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55349948; called by muse, mutect2, varscan2
- EPHA10 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60402201; called by muse, mutect2, varscan2
- EPHX3 | c.1033del p.Q345Rfs*51 | Frame Shift Del (DEL) | VAF 20/77 reads (26%) | catalogued as rs770539760; called by mutect2, pindel, varscan2
- EPPK1 | c.2303T>C p.F768S | Missense Mutation (SNP) | VAF 36/159 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV73260938; called by muse, mutect2, varscan2
- EPS8L1 | c.1229C>T p.P410L (on ENST00000201647 / NM_133180.3; = p.P283L on NM_017729.3) | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs750369259, COSV52380551; called by muse, mutect2, varscan2
- EPX | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.025); catalogued as rs1297380721; called by muse, mutect2
- ERCC3 | c.2183T>A p.V728E | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53426052; called by muse, mutect2, varscan2
- ERF | c.1573del p.L525Sfs*6 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | catalogued as COSV55896967; called by mutect2, pindel
- ERICH3 | c.2713G>T p.A905S | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.038); catalogued as COSV58601773; called by muse, mutect2, varscan2
- ERVFRD-1 | c.574T>G p.F192V | Missense Mutation (SNP) | VAF 54/176 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as COSV65368729; called by muse, mutect2, varscan2
- ESYT2 | c.1847T>C p.L616P (on ENST00000613624; = p.L540P on NM_020728.3) | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV51748615; called by muse, mutect2, varscan2
- ETV3L | c.574G>A p.G192R | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV71901001; called by muse, mutect2, varscan2
- EVPL | c.4285C>A p.R1429S | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as COSV56908573; called by muse, mutect2, varscan2
- EWSR1 | c.1439C>T p.P480L | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.981); catalogued as COSV100132215; called by muse, mutect2, varscan2
- EXOC3 | c.2057C>T p.P686L | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59265996; called by muse, mutect2, varscan2
- F9 | c.1142C>T p.T381I | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.593); catalogued as rs1258831035, CM071733, COSV54379236; called by muse, mutect2, varscan2
- FAM107B | c.259C>T p.R87W (on ENST00000378458 / NM_001320737.1; = p.R262W on NM_031453.3) | Missense Mutation (SNP) | VAF 34/260 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as rs757704900, COSV51678999; called by muse, varscan2
- FAM110C | c.797G>A p.G266D | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.053); catalogued as rs1412530671, COSV100566881, COSV59655660; called by muse, mutect2, varscan2
- FAM131C | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs779836063, COSV65152927; called by muse, mutect2, varscan2
- FAM135B | c.366G>A p.Q122= | Splice Region (SNP) | VAF 11/101 reads (11%) | catalogued as COSV50523423, COSV99358414; called by muse, mutect2, varscan2
- FAM13B | c.2494C>T p.R832* | Nonsense Mutation (SNP) | VAF 38/161 reads (24%) | catalogued as COSV50364567; called by muse, mutect2, varscan2
- FAM161B | c.517G>T p.D173Y (on ENST00000651776; = p.D110Y on NM_152445.3) | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV53178116; called by muse, mutect2, varscan2
- FAM169A | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.712); catalogued as rs1296441351, COSV100998447, COSV65846803; called by muse, varscan2
- FAM222B | c.719del p.P240Rfs*3 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | catalogued as COSV100368550, COSV100368697; called by mutect2, pindel, varscan2
- FAM234B | c.1292C>A p.P431H | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52193445, COSV52196198; called by muse, mutect2, varscan2
- FAM24A | c.131C>A p.A44E | Missense Mutation (SNP) | VAF 44/142 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as rs1399489879, COSV100925094; called by muse, varscan2
- FAM71A | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.277); catalogued as rs753228806, COSV54234919; called by muse, mutect2, varscan2
- FAM71D | c.773C>T p.P258L | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.9); catalogued as rs780986907, COSV61294834; called by muse, mutect2, varscan2
- FAM83A | c.740C>T p.S247L | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.833); catalogued as rs949656741, COSV52684463; called by muse, mutect2, varscan2
- FAM86B1 | c.403G>A p.G135S | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.896); catalogued as rs1323748069, COSV100392578; called by muse, mutect2, varscan2
- FAM98A | c.522del p.K174Nfs*2 | Frame Shift Del (DEL) | VAF 7/51 reads (14%) | catalogued as rs1237814873; called by mutect2, varscan2
- FAM9A | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 129/335 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.383); catalogued as COSV66813033; called by muse, mutect2, varscan2
- FANCF | c.1102A>G p.S368G | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV59415767; called by muse, mutect2
- FANCL | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV52073256; called by muse, mutect2, varscan2
- FAT1 | c.8798_8799insC p.Q2933Hfs*14 | Frame Shift Ins (INS) | VAF 22/72 reads (31%) | catalogued as COSV71672671; called by mutect2, pindel*, varscan2
- FAT1 | c.7535T>C p.M2512T | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV71672672; called by muse, mutect2, varscan2
- FAT4 | c.5417G>A p.R1806H | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs781638960, COSV58677237; called by mutect2, varscan2
- FBN3 | c.5701G>T p.G1901C | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54455660, COSV99560426; called by muse, mutect2, varscan2
- FBXL6 | c.1327C>T p.R443* | Nonsense Mutation (SNP) | VAF 14/63 reads (22%) | catalogued as rs782205578, COSV57351103; called by muse, mutect2, varscan2
- FBXL7 | c.388C>T p.P130S | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.96); PolyPhen benign (0.003); catalogued as COSV100311228; called by muse, mutect2, varscan2
- FBXO24 | c.555G>T p.K185N (on ENST00000241071 / NM_033506.3; = p.K223N on NM_012172.5) | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); catalogued as COSV53825829, COSV53826170; called by muse, mutect2
- FBXO5 | c.329C>T p.T110I | Missense Mutation (SNP) | VAF 31/162 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.157); catalogued as COSV57670544, COSV57671829, COSV99999891; called by muse, mutect2, varscan2
- FBXW5 | c.14G>A p.G5D | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.18); PolyPhen benign (0.025); catalogued as rs769398170, COSV99812730; called by muse, mutect2, varscan2
- FDXR | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.028); catalogued as rs756259973, COSV99502551; called by muse, mutect2, varscan2
- FGD4 | c.1814G>A p.G605D | Missense Mutation (SNP) | VAF 45/149 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.515); catalogued as rs886049255, COSV99847791; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FGFR2 | c.376G>T p.D126Y | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as COSV60659966; called by muse, mutect2, varscan2
- FHOD1 | c.1525C>T p.R509* | Nonsense Mutation (SNP) | VAF 8/54 reads (15%) | catalogued as rs369969027, COSV50759234; called by mutect2, varscan2
- FHOD1 | c.1126C>T p.R376C | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as COSV50759244; called by muse, mutect2, varscan2
- FHOD3 | c.118G>A p.G40S | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.55); PolyPhen benign (0.323); catalogued as COSV57167267; called by muse, mutect2, varscan2
- FIBIN | c.457C>T p.R153W | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs759764078, COSV59412499, COSV59413519; called by muse, mutect2, varscan2
- FKBP10 | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs993652435, COSV58635389; called by muse, varscan2
- FLAD1 | c.378C>G p.H126Q | Missense Mutation (SNP) | VAF 51/138 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.029); catalogued as COSV52696086; called by muse, mutect2, varscan2
- FLG | c.4872G>T p.E1624D | Missense Mutation (SNP) | VAF 23/294 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0.125); catalogued as COSV100912469; called by muse, mutect2
- FLNC | c.1676+2T>C p.X559_splice | Splice Site (SNP) | VAF 19/124 reads (15%) | catalogued as COSV100369006; called by muse, mutect2, varscan2
- FLNC | c.1760G>T p.G587V | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100369007; called by muse, mutect2
- FLNC | c.7090C>T p.R2364C | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.984); catalogued as rs374973240; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLRT1 | c.520G>A p.A174T | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.617); catalogued as rs1163223569, COSV55356757; called by muse, mutect2, varscan2
- FMN2 | c.2344T>C p.C782R | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.862); catalogued as COSV100147921; called by muse, mutect2, varscan2
- FMO5 | c.746G>A p.G249D | Missense Mutation (SNP) | VAF 52/160 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.155); catalogued as COSV54205060; called by muse, mutect2, varscan2
- FMOD | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.62); PolyPhen benign (0.01); catalogued as COSV61609769; called by muse, mutect2, varscan2
- FNDC3A | c.3353T>C p.V1118A (on ENST00000492622 / NM_001079673.2; = p.V1062A on NM_014923.5) | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.157); catalogued as COSV101257043; called by muse, mutect2, varscan2
- FOXD4L1 | c.211C>T p.R71* | Nonsense Mutation (SNP) | VAF 42/117 reads (36%) | catalogued as COSV52073307; called by muse, mutect2, varscan2
- FOXK1 | c.565A>G p.T189A | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.744); catalogued as COSV61064896; called by muse, mutect2, varscan2
- FOXL2 | c.227C>T p.T76M | Missense Mutation (SNP) | VAF 50/114 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57725388; called by muse, mutect2, varscan2
- FOXO1 | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 29/175 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1034299550, COSV65425761; called by muse, mutect2, varscan2
- FRAS1 | c.8737G>A p.D2913N | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV53596348; called by muse, mutect2
- FREM2 | c.1912C>T p.R638* | Nonsense Mutation (SNP) | VAF 11/51 reads (22%) | catalogued as COSV99751628; called by muse, mutect2, varscan2
- FRG1 | c.591_593del p.E197del | In Frame Del (DEL) | VAF 26/228 reads (11%) | catalogued as rs56257823; called by pindel, varscan2
- FRMD3 | c.607C>T p.P203S | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.264); catalogued as COSV58454985; called by muse, mutect2, varscan2
- FRYL | c.2486C>T p.A829V | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT tolerated (0.77); PolyPhen benign (0.036); catalogued as COSV51942052; called by muse, mutect2, varscan2
- FRZB | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99717621; called by muse, mutect2, varscan2
- FSIP2 | c.19967A>G p.Y6656C | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100556956; called by muse, mutect2, varscan2
- FSTL5 | c.88C>T p.L30F | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as COSV60184891; called by muse, mutect2, varscan2
- FTSJ3 | c.1596G>T p.K532N | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV63789590; called by muse, mutect2
- FUBP3 | c.1675G>A p.G559R | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as rs372245867; called by muse, mutect2, varscan2
- FUCA1 | c.871C>T p.H291Y | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV65698801; called by muse, varscan2
- FXR1 | c.899del p.N300Mfs*8 | Frame Shift Del (DEL) | VAF 23/199 reads (12%) | catalogued as COSV59765067; called by mutect2, varscan2
- FXR1 | c.1810A>G p.N604D | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV99976758; called by muse, varscan2
- FYB2 | c.1307A>T p.K436M | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV58583421; called by muse, mutect2, varscan2
- FZD6 | c.935G>T p.G312V | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.889); catalogued as COSV100708533; called by muse, mutect2, varscan2
- GABPB1 | c.437A>C p.D146A | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.237); catalogued as COSV99590263; called by muse, mutect2
- GABRA4 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 83/268 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.262); catalogued as rs138764484; called by muse, varscan2
- GABRA5 | c.240C>A p.Y80* | Nonsense Mutation (SNP) | VAF 9/32 reads (28%) | catalogued as COSV100165971; called by muse, mutect2, varscan2
- GABRD | c.893G>A p.R298H | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66080349; called by muse, mutect2, varscan2
- GALNT10 | c.1280G>A p.R427H | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1561686498, COSV51720748; called by muse, mutect2, varscan2
- GAPDHS | c.373G>A p.G125S | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.763); catalogued as rs202137889; called by muse, mutect2, varscan2
- GATAD2A | c.1835G>A p.R612H | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1382309211, COSV53067733, COSV99389659; called by muse, mutect2, varscan2
- GCN1 | c.5380C>T p.R1794C | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1459990599, COSV56105039; called by muse, mutect2, varscan2
- GCNT4 | c.80C>T p.S27F | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.325); catalogued as COSV59280556; called by muse, mutect2, varscan2
- GDF1 | c.1015C>T p.P339S | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs865998453, COSV99440648; called by muse, varscan2
- GEMIN5 | c.2857G>T p.A953S | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.056); catalogued as COSV99594459; called by mutect2, varscan2
- GFAP | c.730G>A p.A244T | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.999); catalogued as COSV53649389; called by muse, mutect2, varscan2
- GFM1 | c.115G>T p.G39W | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV99963279; called by muse, mutect2, varscan2
- GGA1 | c.1430A>G p.H477R | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV57329296; called by muse, mutect2, varscan2
- GID4 | c.631T>C p.Y211H | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV52008308; called by muse, mutect2, varscan2
- GLB1L2 | c.1436C>T p.T479I | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV60277853; called by muse, mutect2, varscan2
- GLB1L3 | c.1265A>T p.D422V | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV68392470; called by muse, mutect2, varscan2
- GLI3 | c.1345C>T p.R449W | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.757); catalogued as rs769783770, COSV67886171; called by muse, mutect2, varscan2
- GLRA1 | c.844G>A p.G282S | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.648); catalogued as COSV51008529; called by muse, mutect2, varscan2
- GMEB2 | c.1103C>T p.P368L | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs763512161, COSV99823948; called by muse, mutect2, varscan2
- GNB3 | c.955G>T p.G319* | Nonsense Mutation (SNP) | VAF 7/31 reads (23%) | catalogued as COSV99977170; called by muse, mutect2, varscan2
- GNPAT | c.628C>T p.R210W | Missense Mutation (SNP) | VAF 47/166 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199523352, COSV64153558; called by muse, mutect2, varscan2
- GNPAT | c.1622A>G p.Y541C | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.775); catalogued as COSV64153099; called by muse, mutect2, varscan2
- GNRH1 | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as CM094311, COSV52382512; called by muse, mutect2, varscan2
- GOPC | c.1074G>T p.Q358H | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV50000917; called by muse, mutect2, varscan2
- GORASP1 | c.937A>T p.I313F | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV100073389; called by muse, mutect2, varscan2
- GPAT3 | c.1109C>T p.P370L | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs772639676, COSV52355850; called by muse, mutect2, varscan2
- GPC1 | c.452A>G p.Y151C | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50862841; called by muse, mutect2, varscan2
- GPR142 | c.456del p.C153Vfs*24 | Frame Shift Del (DEL) | VAF 30/121 reads (25%) | catalogued as COSV59518876; called by mutect2, pindel, varscan2
- GPR158 | c.3454C>T p.R1152C | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.183); catalogued as rs368132351, COSV100893879; called by muse, mutect2, varscan2
- GPR160 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs372339784, COSV63472725; called by muse, mutect2, varscan2
- GRAMD1B | c.1586G>A p.R529H | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs538509009, COSV59201542; called by muse, mutect2, varscan2
- GRB7 | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs767188773, COSV58446734; called by muse, mutect2, varscan2
- GRIA1 | c.1135-1G>A p.X379_splice | Splice Site (SNP) | VAF 18/56 reads (32%) | catalogued as COSV53593222; called by muse, mutect2, varscan2
- GRID2 | c.2972C>T p.P991L | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV56223242; called by muse, mutect2, varscan2
- GRIK3 | c.2308C>T p.P770S | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66136703; called by muse, mutect2, varscan2
- GRIK5 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1445515358, COSV99491569; called by muse, mutect2, varscan2
- GRIPAP1 | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.06); catalogued as COSV64551296; called by muse, mutect2, varscan2
- GRM3 | c.1138G>A p.D380N | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs967635794, COSV64468638; called by muse, mutect2, varscan2
- GRM6 | c.727dup p.V243Gfs*40 | Frame Shift Ins (INS) | VAF 13/52 reads (25%) | catalogued as rs281865186; ClinVar: not provided; called by mutect2, varscan2
- GSE1 | c.1858G>A p.V620M | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.804); catalogued as rs774753192, COSV53669869; called by muse, varscan2
- GSPT2 | c.793A>G p.K265E | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61213848; called by muse, mutect2
- GTF2E1 | c.1295G>A p.R432H | Missense Mutation (SNP) | VAF 59/184 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.602); catalogued as rs781010638, COSV52203570; called by muse, mutect2, varscan2
- H1-2 | c.568G>A p.A190T | Missense Mutation (SNP) | VAF 32/220 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs1018305284, COSV100642343; called by muse, mutect2, varscan2
- H4C12 | c.59G>A p.R20H | Missense Mutation (SNP) | VAF 36/169 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.306); catalogued as rs781309459, COSV100694834; called by muse, varscan2
- H6PD | c.1402G>T p.G468C | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.078); catalogued as COSV66230481; called by mutect2, varscan2
- HASPIN | c.923C>T p.A308V | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as rs533560843, COSV53990496; called by muse, mutect2, varscan2
- HCFC1 | c.5950G>A p.A1984T | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV60070190; called by muse, mutect2, varscan2
- HCN2 | c.1426T>C p.Y476H | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV52113056; called by muse, mutect2, varscan2
- HCN4 | c.3531del p.P1179Lfs*2 | Frame Shift Del (DEL) | VAF 13/70 reads (19%) | catalogued as rs749503920, COSV56083147; called by mutect2, pindel, varscan2
- HCN4 | c.2003G>A p.R668Q | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as rs757268783, COSV56082007; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HDAC5 | c.2793del p.I932Lfs*14 | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | catalogued as COSV52242263; called by mutect2, pindel, varscan2
- HDX | c.578C>T p.A193V | Missense Mutation (SNP) | VAF 19/158 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.014); catalogued as COSV52974064; called by muse, mutect2, varscan2
- HEATR1 | c.2852C>T p.P951L | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs150392772, COSV63979978; called by muse, mutect2, varscan2
- HECTD1 | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101237590; called by muse, mutect2
- HECW1 | c.804A>G p.Q268= | Splice Region (SNP) | VAF 18/60 reads (30%) | catalogued as rs368494869; called by muse, varscan2
- HERC1 | c.7874A>G p.D2625G | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV101497110; called by muse, mutect2, varscan2
- HERC1 | c.3324G>T p.Q1108H | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV71246644; called by muse, mutect2, varscan2
- HEXA | c.723G>T p.E241D | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1435809210, COSV51505611; called by muse, mutect2, varscan2
- HGS | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as COSV61266998; called by muse, mutect2, varscan2
- HHATL | c.112G>C p.A38P | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.36); catalogued as COSV100124747; called by muse, mutect2, varscan2
- HIC2 | c.773del p.P258Lfs*16 | Frame Shift Del (DEL) | VAF 8/43 reads (19%) | catalogued as COSV68041887; called by mutect2, pindel, varscan2
- HLA-A | c.686C>A p.A229D | Missense Mutation (SNP) | VAF 54/202 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV65138433; called by muse, varscan2
- HNF1A | c.1498del p.H500Tfs*31 | Frame Shift Del (DEL) | VAF 12/81 reads (15%) | catalogued as CM995175; called by mutect2, pindel, varscan2
- HOXB2 | c.623C>T p.P208L | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs758702144, COSV57486104; called by muse, mutect2, varscan2
- HOXB3 | c.832G>A p.A278T | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.122); catalogued as COSV57486108; called by muse, mutect2, varscan2
- HOXC13 | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54498268; called by muse, mutect2, varscan2
- HP1BP3 | c.1367+2T>C p.X456_splice | Splice Site (SNP) | VAF 32/131 reads (24%) | catalogued as COSV56561573; called by muse, mutect2, varscan2
- HPCA | c.352C>T p.R118W | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs1333008899, COSV100992158, COSV65102808; called by muse, mutect2, varscan2
- HPS1 | c.379G>A p.G127S | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs371321032, COSV57269004; called by muse, varscan2
- HROB | c.1601C>T p.T534M | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as rs776309501, COSV55369027; called by muse, mutect2, varscan2
- HS6ST3 | c.1045G>A p.A349T | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.953); catalogued as COSV65004302; called by muse, mutect2, varscan2
- HSD17B8 | c.673G>T p.G225* | Nonsense Mutation (SNP) | VAF 20/56 reads (36%) | catalogued as COSV63002361; called by muse, mutect2, varscan2
- HSPA1L | c.715C>G p.L239V | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.993); catalogued as COSV65148754; called by muse, mutect2, varscan2
- HTRA4 | c.79C>T p.L27F | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.71); PolyPhen benign (0.03); catalogued as rs1267167507, COSV56758427; called by muse, varscan2
- HTT | c.5175A>T p.E1725D | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV61858744; called by muse, mutect2, varscan2
- HYDIN | c.9991G>A p.E3331K | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as rs201494207; called by muse, mutect2, varscan2
- IARS1 | c.360C>A p.C120* | Nonsense Mutation (SNP) | VAF 25/137 reads (18%) | catalogued as COSV65114338; called by muse, mutect2, varscan2
- IDH3G | c.499C>T p.R167W | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54206428; called by muse, mutect2, varscan2
- IDO2 | c.824A>G p.H275R (on ENST00000389060; = p.H288R on NM_194294.2) | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as rs1236549130, COSV58424247; called by muse, mutect2, varscan2
- IFNA13 | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 64/197 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.119); catalogued as COSV101489541; called by muse, mutect2, varscan2
- IFT140 | c.2590C>T p.Q864* | Nonsense Mutation (SNP) | VAF 18/61 reads (30%) | catalogued as COSV54151977; called by muse, mutect2, varscan2
- IFT172 | c.3374C>T p.S1125F | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as rs867680794, COSV53131073; called by muse, mutect2, varscan2
- IFT27 | c.550G>A p.A184T (on ENST00000433985 / NM_001363003.2; = p.A183T on NM_006860.5) | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV61416038; called by muse, mutect2, varscan2
- IGF2R | c.3949del p.D1317Tfs*27 | Frame Shift Del (DEL) | VAF 24/62 reads (39%) | catalogued as rs760021495; called by mutect2, varscan2
- IGHA1 | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 45/132 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.975); catalogued as rs367887608; called by muse, mutect2, varscan2
- IGHV1-46 | c.233G>A p.S78N | Missense Mutation (SNP) | VAF 77/178 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs567613988; called by muse, mutect2, varscan2
- IGHV3-23 | c.29T>A p.L10H | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs781827685; called by muse, mutect2, varscan2
- IGSF3 | c.78G>T p.Q26H | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59587905; called by muse, mutect2, varscan2
- IGSF5 | c.826C>A p.L276I | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.35); catalogued as COSV66029573; called by muse, mutect2, varscan2
- IGSF9 | c.2464del p.D822Ifs*33 (on ENST00000368094 / NM_001135050.2; = p.D806Ifs*33 on NM_020789.4) | Frame Shift Del (DEL) | VAF 11/38 reads (29%) | catalogued as COSV57423607; called by mutect2, pindel, varscan2
- IL1RAP | c.661C>T p.R221C | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs150231780; called by muse, mutect2, varscan2
- IL2RG | c.1082del p.P361Hfs*5 | Frame Shift Del (DEL) | VAF 16/108 reads (15%) | catalogued as rs745545309; called by mutect2, varscan2
- IL2RG | c.597A>T p.E199D | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.232); catalogued as COSV99340469; called by muse, mutect2, varscan2
- IL4I1 | c.1475C>T p.T492M | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1452795602, COSV55577689; called by muse, mutect2, varscan2
- IL6ST | c.1587del p.V530* | Frame Shift Del (DEL) | VAF 56/194 reads (29%) | catalogued as rs776023104; called by mutect2, varscan2
- IMPA2 | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs369866405; called by mutect2, varscan2
- ING1 | c.1192A>T p.K398* | Nonsense Mutation (SNP) | VAF 19/161 reads (12%) | catalogued as COSV58167335; called by muse, mutect2, varscan2
- INPP1 | c.650G>A p.G217E | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59415229; called by muse, mutect2
- INPP4B | c.2654G>A p.R885H | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs568595082, COSV53715220; called by muse, varscan2
- INPP5F | c.2698C>T p.R900* | Nonsense Mutation (SNP) | VAF 18/69 reads (26%) | catalogued as rs146380100; called by muse, mutect2, varscan2
- INSRR | c.2109G>T p.E703D | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.351); catalogued as COSV63871518; called by muse, mutect2, varscan2
- IPO4 | c.1849C>T p.R617C | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs755630919, COSV61015531; called by muse, mutect2, varscan2
- IQGAP2 | c.506T>C p.L169S | Missense Mutation (SNP) | VAF 95/308 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as COSV57169660; called by muse, mutect2, varscan2
- IQGAP2 | c.847_848del p.D283Cfs*3 | Frame Shift Del (DEL) | VAF 54/204 reads (26%) | catalogued as rs1343321555; called by pindel, varscan2
- IQGAP3 | c.4411C>T p.R1471C | Missense Mutation (SNP) | VAF 56/146 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs748938834, COSV100752483; called by muse, mutect2, varscan2
- IRF2 | c.704C>T p.T235M | Missense Mutation (SNP) | VAF 46/144 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs779259983, COSV66928877; called by muse, mutect2, varscan2
- ITGA9 | c.950G>A p.G317D | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99294192; called by muse, mutect2, varscan2
- ITGB4 | c.2530C>T p.R844C | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs149608383; called by muse, mutect2, varscan2
- ITIH3 | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs768027400, COSV56253093; called by muse, mutect2, varscan2
- ITPR1 | c.5419C>A p.L1807I (on ENST00000354582; = p.L1752I on NM_002222.7) | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.291); catalogued as COSV56973245; called by muse, mutect2, varscan2
- ITPR2 | c.2082G>A p.W694* | Nonsense Mutation (SNP) | VAF 43/158 reads (27%) | catalogued as COSV67266360; called by muse, mutect2, varscan2
- ITPRIPL2 | c.1370G>A p.G457D | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV67347422; called by muse, mutect2, varscan2
- ITSN2 | c.812C>T p.A271V | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.95); catalogued as COSV61944657; called by muse, mutect2, varscan2
- JADE1 | c.124C>T p.R42* | Nonsense Mutation (SNP) | VAF 25/100 reads (25%) | catalogued as COSV56904736; called by muse, mutect2, varscan2
- JADE1 | c.380_381del p.G127Vfs*9 | Frame Shift Del (DEL) | VAF 18/84 reads (21%) | catalogued as COSV56904745; called by mutect2, pindel, varscan2
- JAG1 | c.2200G>A p.G734S | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs199561320, COSV99653641; called by muse, varscan2
- JAKMIP1 | c.806G>A p.G269E | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.643); catalogued as COSV51524451; called by muse, mutect2, varscan2
- JRK | c.1114G>A p.A372T | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs782289704, COSV70629728; called by muse, mutect2, varscan2
- JRKL | c.1477G>A p.E493K | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs773941823, COSV99567641; called by mutect2, varscan2
- KALRN | c.8374C>T p.Q2792* (on ENST00000360013 / NM_001024660.4; = p.Q1095* on NM_007064.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 11/56 reads (20%) | catalogued as COSV52263617; called by muse, mutect2, varscan2
- KAT14 | c.965C>T p.P322L | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs1046456317, COSV66606895; called by muse, mutect2, varscan2
- KATNIP | c.3109G>A p.G1037R | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs780495694, COSV99852275; called by muse, mutect2, varscan2
- KBTBD12 | c.1835del p.P612Rfs*78 | Frame Shift Del (DEL) | VAF 13/70 reads (19%) | catalogued as rs1187501286, COSV100675484; called by mutect2, pindel, varscan2
- KCNA5 | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.273); catalogued as rs121908590, CM062782, COSV52904382; called by muse, mutect2, varscan2
- KCNH7 | c.3191C>T p.T1064I | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0.117); catalogued as COSV59789891; called by muse, mutect2, varscan2
- KCNJ9 | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.55); PolyPhen benign (0.019); catalogued as rs756062305, COSV100081878; called by mutect2, varscan2
- KCNK17 | c.503del p.G168Afs*61 | Frame Shift Del (DEL) | VAF 18/53 reads (34%) | catalogued as COSV64685346; called by mutect2, pindel, varscan2
- KCNK5 | c.1355G>T p.G452V | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV63988670; called by muse, mutect2, varscan2
- KCNN2 | c.1209A>C p.E403D (on ENST00000264773; = p.E615D on NM_021614.4) | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV53284855, COSV53302103; called by muse, mutect2
- KCNT1 | c.289C>T p.R97W (on ENST00000488444; = p.R116W on NM_020822.3) | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53697267; called by muse, mutect2, varscan2
- KCNV1 | c.991G>T p.G331* | Nonsense Mutation (SNP) | VAF 10/38 reads (26%) | catalogued as COSV52085061; called by muse, mutect2, varscan2
- KCTD15 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.438); catalogued as COSV52289276; called by muse, mutect2, varscan2
- KDM1B | c.1078G>T p.G360C (on ENST00000449850; = p.G228C on NM_153042.4) | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52809129; called by muse, mutect2, varscan2
- KDM4C | c.811A>T p.I271F | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101185240; called by muse, mutect2
- KDM6A | c.3331C>T p.R1111C | Missense Mutation (SNP) | VAF 28/205 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs763592177, COSV65038074, COSV65038305, COSV65040911, COSV65042699; called by muse, varscan2
- KDM6B | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs748522794, COSV54678909; called by muse, varscan2
- KHSRP | c.1459G>A p.A487T | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101231265; called by muse, mutect2, varscan2
- KIAA0408 | c.1961C>A p.A654D | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100847598; called by muse, mutect2, varscan2
- KIAA0895 | c.1027A>T p.N343Y (on ENST00000297063 / NM_001100425.2; = p.N292Y on NM_015314.3) | Missense Mutation (SNP) | VAF 42/286 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51709363; called by muse, mutect2, varscan2
- KIAA1109 | c.12416C>T p.T4139I | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.399); catalogued as COSV52665438; called by muse, mutect2, varscan2
- KIAA1217 | c.635C>T p.A212V | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64602519; called by muse, mutect2, varscan2
- KIAA1217 | c.3824C>T p.P1275L | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV100286317, COSV56813675; called by muse, mutect2, varscan2
- KIAA1522 | c.172del p.H58Tfs*24 (on ENST00000373480 / NM_001198972.2; = p.H117Tfs*24 on NM_020888.3) | Frame Shift Del (DEL) | VAF 9/106 reads (8%) | catalogued as rs767600627; called by pindel, varscan2*
- KIF16B | c.3499C>T p.R1167W | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as rs201827988, COSV61702616, COSV61710600; called by muse, mutect2, varscan2
- KIF1B | c.2627G>A p.G876D (on ENST00000377086 / NM_001365952.1; = p.G830D on NM_015074.3) | Missense Mutation (SNP) | VAF 42/149 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs1353851331, COSV55804914, COSV99822985; called by muse, varscan2
- KIF21A | c.2148del p.V717Lfs*12 (on ENST00000361418 / NM_001378440.1; = p.V704Lfs*12 on NM_017641.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 40/156 reads (26%) | catalogued as rs1193021160; called by mutect2, varscan2
- KIF21B | c.3565C>T p.R1189W | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.518); catalogued as rs376964063, COSV59754147; called by muse, mutect2, varscan2
- KIF4A | c.875A>C p.K292T | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100979668; called by muse, mutect2, varscan2
- KIF4B | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 47/234 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as rs774743075, COSV70528391, COSV70530194; called by muse, mutect2, varscan2
- KIFAP3 | c.1244G>A p.R415H | Missense Mutation (SNP) | VAF 66/232 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.467); catalogued as rs763167127, COSV63030701; called by muse, mutect2, varscan2
- KIRREL1 | c.1179del p.I394Sfs*11 | Frame Shift Del (DEL) | VAF 24/114 reads (21%) | catalogued as COSV63290909; called by mutect2, pindel, varscan2
- KIT | c.2702A>G p.D901G | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.501); catalogued as COSV55392501; called by muse, mutect2, varscan2
- KLF3 | c.677del p.P226Rfs*52 | Frame Shift Del (DEL) | VAF 14/58 reads (24%) | catalogued as COSV54711577; called by mutect2, pindel, varscan2
- KLHDC8A | c.17T>C p.V6A | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1378053237, COSV65678382; called by muse, mutect2, varscan2
- KLHL25 | c.1454C>T p.T485I | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.61); PolyPhen benign (0.105); catalogued as COSV61994457; called by muse, mutect2, varscan2
- KLHL4 | c.1899C>A p.C633* | Nonsense Mutation (SNP) | VAF 21/162 reads (13%) | catalogued as COSV100910285, COSV64142399; called by muse, mutect2, varscan2
- KLHL5 | c.173A>G p.Q58R | Missense Mutation (SNP) | VAF 57/154 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as COSV99786137; called by muse, varscan2
- KLHL5 | c.603T>G p.N201K | Missense Mutation (SNP) | VAF 32/222 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.036); catalogued as COSV54672428; called by muse, varscan2
- KLK8 | c.419G>A p.S140N | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99144138; called by muse, mutect2, varscan2
- KMT2A | c.9255G>A p.M3085I | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.038); catalogued as COSV63283204; called by muse, mutect2, varscan2
- KMT2D | c.9790C>A p.Q3264K | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as rs1009925927, COSV56420101; called by muse, mutect2, varscan2
- KPTN | c.1078C>T p.R360W | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as rs370453813; called by muse, mutect2, varscan2
- KPTN | c.823G>A p.V275M | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.241); catalogued as rs373073023; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KPTN | c.273del p.K92Sfs*22 | Frame Shift Del (DEL) | VAF 12/34 reads (35%) | catalogued as COSV99645797; called by mutect2, pindel, varscan2
- KRT1 | c.515A>T p.E172V | Missense Mutation (SNP) | VAF 63/256 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV99359053; called by muse, varscan2
- KRT1 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 64/254 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.636); catalogued as rs1445264570, COSV52865490; called by muse, mutect2, varscan2
- KRT5 | c.1234A>G p.N412D | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as COSV99358357; called by muse, mutect2, varscan2
- KRT85 | c.292G>A p.V98M | Missense Mutation (SNP) | VAF 74/208 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57736211; called by muse, mutect2, varscan2
- KRTAP19-3 | c.83G>A p.G28E | Missense Mutation (SNP) | VAF 40/127 reads (31%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.887); catalogued as COSV100477597, COSV61854590; called by muse, mutect2, varscan2
- KRTAP27-1 | c.164A>G p.N55S | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV67001005; called by muse, mutect2, varscan2
- LAMA1 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT tolerated (0.83); PolyPhen possibly damaging (0.87); catalogued as rs375547281; called by muse, mutect2, varscan2
- LAMA2 | c.8625dup p.A2876Sfs*30 | Frame Shift Ins (INS) | VAF 43/162 reads (27%) | catalogued as rs749162150; called by mutect2, pindel, varscan2
- LAMA3 | c.3995C>T p.T1332M | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs745375536, COSV58064095; called by muse, mutect2, varscan2
- LAMB1 | c.5306G>A p.R1769H | Missense Mutation (SNP) | VAF 63/178 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as rs748443031, COSV52737198; called by muse, varscan2
- LAMP1 | c.1169G>A p.G390D | Missense Mutation (SNP) | VAF 45/83 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1264823922, COSV58149080; called by muse, mutect2, varscan2
- LARGE1 | c.1339C>T p.R447W | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1460224950, COSV61659030; called by muse, mutect2, varscan2
- LARGE2 | c.1241G>A p.R414H | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs568405351, COSV57650966; called by muse, mutect2, varscan2
- LATS1 | c.2645C>A p.P882H | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.629); catalogued as COSV53587565; called by muse, mutect2, varscan2
- LATS2 | c.47G>A p.R16Q | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.994); catalogued as rs1285144450, COSV66874049, COSV66876520; called by muse, mutect2
- LCE2B | c.38del p.P13Lfs*61 | Frame Shift Del (DEL) | VAF 25/116 reads (22%) | catalogued as rs1188093001; called by mutect2, pindel, varscan2
- LDB1 | c.1211C>T p.T404M (on ENST00000425280 / NM_001321612.2; = p.T370M on NM_003893.5) | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.681); catalogued as rs773354858, COSV63288795; called by muse, mutect2, varscan2
- LGALS3BP | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.192); catalogued as COSV99432031; called by muse, mutect2, varscan2
- LGI1 | c.626G>A p.R209H | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as rs370151711; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LGSN | c.1280G>A p.G427D | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1470921513, COSV65726460; called by muse, mutect2, varscan2
- LHCGR | c.464T>G p.I155S | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV54294022; called by muse, mutect2, varscan2
- LHFPL6 | c.124del p.V42Cfs*20 | Frame Shift Del (DEL) | VAF 10/90 reads (11%) | catalogued as COSV65444292; called by mutect2, pindel
- LHPP | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs771378730, COSV100919365, COSV64328552; called by muse, mutect2, varscan2
- LHX1 | c.1194del p.E399Kfs*2 | Frame Shift Del (DEL) | VAF 8/37 reads (22%) | catalogued as rs775423572; called by mutect2, pindel, varscan2
- LILRB2 | c.1283del p.P428Hfs*35 | Frame Shift Del (DEL) | VAF 44/122 reads (36%) | catalogued as rs1281849477; called by mutect2, varscan2
- LINGO3 | c.512C>T p.A171V | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.028); catalogued as COSV68261050; called by muse, mutect2, varscan2
- LIPE | c.2429G>A p.R810Q | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs150433777; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LMO7 | c.1415G>T p.R472M (on ENST00000357063; = p.R202M on NM_015842.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV58531739; called by muse, mutect2, varscan2
- LPL | c.1108G>A p.V370M | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.298); catalogued as rs298, CM1213431, COSV60930454; called by muse, mutect2, varscan2
- LRRC7 | c.3838G>A p.D1280N (on ENST00000651989 / NM_001370785.2; = p.D1247N on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.832); catalogued as COSV99230681; called by muse, mutect2, varscan2
- LRRC7 | c.3840C>A p.D1280E (on ENST00000651989 / NM_001370785.2; = p.D1247E on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.78); PolyPhen benign (0.033); catalogued as COSV50421694; called by muse, mutect2, varscan2
- LRRC75B | c.838C>A p.L280M | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated (0.06); PolyPhen benign (0.052); catalogued as COSV50638547; called by muse, mutect2, varscan2
- LRRFIP2 | c.632T>C p.L211S | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV60866646; called by muse, mutect2, varscan2
- LRTM1 | c.377A>C p.E126A | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.492); catalogued as COSV99836314; called by muse, mutect2
- LSP1 | c.322del p.Q108Sfs*31 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | catalogued as rs752018434; called by pindel, varscan2
- LTBP1 | c.4852G>A p.E1618K (on ENST00000404816 / NM_206943.4; = p.E1292K on NM_000627.4) | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55376803; called by muse, mutect2, varscan2
- LY6G6F-LY6G6D | c.256C>A p.L86M | Missense Mutation (SNP) | VAF 46/143 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV65442597, COSV65442614; called by muse, mutect2, varscan2
- LYST | c.3175G>A p.A1059T | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); catalogued as COSV101090543; called by muse, mutect2, varscan2
- MAB21L2 | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.939); catalogued as COSV100462484; called by muse, mutect2, varscan2
- MACF1 | c.9659G>A p.S3220N | Missense Mutation (SNP) | VAF 16/162 reads (10%) | catalogued as COSV99247666; called by muse, mutect2
- MACF1 | c.19921A>G p.T6641A (on ENST00000372915; = p.T4686A on NM_012090.5) | Missense Mutation (SNP) | VAF 21/62 reads (34%) | catalogued as COSV57110928; called by muse, mutect2, varscan2
- MADD | c.457G>A p.V153M | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.057); catalogued as COSV60621412; called by muse, varscan2
- MAF1 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0.051); catalogued as rs765491765, COSV59362746; called by muse, mutect2, varscan2
- MAGI1 | c.3992G>A p.R1331H | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.66); catalogued as rs1185164227, COSV58318143; called by muse, mutect2, varscan2
- MAK | c.1100C>T p.P367L | Missense Mutation (SNP) | VAF 34/410 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs776680313, COSV57564466; called by muse, mutect2
- MAMDC2 | c.1463A>G p.D488G | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.46); catalogued as COSV101014036; called by muse, mutect2, varscan2
- MAN1A1 | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs1460288261, COSV100870453; called by muse, mutect2
- MAP2 | c.3671C>T p.T1224M | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.018); catalogued as rs149194467; called by muse, mutect2, varscan2
- MAP2 | c.4807C>T p.P1603S | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs961813289, COSV99562159; called by muse, mutect2, varscan2
- MAP3K13 | c.600G>T p.Q200H | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.617); catalogued as COSV53985172, COSV53991704; called by muse, mutect2, varscan2
- MAP3K2 | c.704C>A p.P235H | Missense Mutation (SNP) | VAF 60/210 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0.013); catalogued as COSV61293340; called by muse, mutect2, varscan2
- MAP3K20 | c.61A>G p.N21D | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.938); catalogued as COSV100169631; called by muse, mutect2, varscan2
- MAP3K4 | c.4547G>A p.R1516H | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as rs773556218, COSV100815765; called by muse, mutect2, varscan2
- MAP7D3 | c.922dup p.Q308Pfs*25 | Frame Shift Ins (INS) | VAF 32/154 reads (21%) | catalogued as rs746202015; called by mutect2, varscan2
- MAPK12 | c.845C>T p.P282L | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.094); catalogued as COSV53132311; called by muse, mutect2, varscan2
- MAPK8 | c.231G>T p.M77I | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.718); catalogued as COSV64408570; called by muse, mutect2, varscan2
- MARCHF7 | c.1463T>C p.V488A | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.371); catalogued as COSV52028031; called by muse, mutect2, varscan2
- MARVELD3 | c.701G>A p.G234D | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51704258; called by muse, mutect2, varscan2
- MAST2 | c.3784C>G p.P1262A | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.2); catalogued as COSV63616527; called by muse, mutect2, varscan2
- MAST4 | c.2303C>T p.A768V (on ENST00000403625 / NM_001164664.2; = p.A579V on NM_015183.3) | Missense Mutation (SNP) | VAF 58/145 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV55118515; called by muse, mutect2, varscan2
- MAX | c.139C>T p.R47W | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866762160, COSV52415682; called by muse, mutect2, varscan2
- MC1R | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.098); catalogued as COSV59624698; called by muse, mutect2, varscan2
- MCMDC2 | c.1322A>C p.K441T | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV58041817; called by muse, mutect2, varscan2
- MDGA1 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1377568505, COSV51793161; called by muse, mutect2, varscan2
- MECOM | c.1839del p.G614Efs*30 (on ENST00000468789 / NM_001105078.4; = p.G802Efs*30 on NM_004991.4) | Frame Shift Del (DEL) | VAF 31/95 reads (33%) | catalogued as rs773080349; called by mutect2, pindel, varscan2
- MECR | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.07); catalogued as rs143281690; called by muse, mutect2, varscan2
- MED13 | c.5911G>A p.V1971I | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.047); catalogued as COSV67262414; called by muse, mutect2, varscan2
- MED14 | c.3286C>A p.P1096T | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100247646, COSV61356202; called by muse, mutect2, varscan2
- MED24 | c.2680C>T p.R894W | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs142219986; called by muse, mutect2, varscan2
- MEGF6 | c.4318del p.A1440Hfs*78 | Frame Shift Del (DEL) | VAF 19/59 reads (32%) | catalogued as rs759225724, COSV53895347; called by mutect2, pindel, varscan2
- MEIS3 | c.976G>A p.D326N (on ENST00000558555 / NM_001346148.1; = p.D372N on NM_020160.3) | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as rs1312686736, COSV58983004; called by muse, mutect2, varscan2
- MERTK | c.1390G>A p.V464I | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as rs148833587; called by muse, mutect2
- MGAM | c.2675A>C p.K892T | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV72073972; called by muse, mutect2, varscan2
- MGAT4B | c.1397del p.T466Sfs*72 | Frame Shift Del (DEL) | VAF 25/75 reads (33%) | catalogued as COSV52977134; called by pindel, varscan2
- MIDEAS | c.1034G>A p.R345H | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs938666507, COSV54099961; called by muse, mutect2, varscan2
- MIDEAS | c.939del p.N314Tfs*4 | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | catalogued as rs762448666; called by mutect2, varscan2
- MIF4GD | c.393C>A p.D131E (on ENST00000325102 / NM_001370592.1; = p.D165E on NM_020679.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.804); catalogued as COSV55453017; called by muse, mutect2, varscan2
- MINDY2 | c.577A>G p.S193G | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.373); catalogued as COSV57505905; called by muse, mutect2, varscan2
- MITF | c.1075C>T p.R359* (on ENST00000448226 / NM_006722.3; = p.R259* on NM_000248.4) | Nonsense Mutation (SNP) | VAF 24/90 reads (27%) | catalogued as CM960963, COSV100097589; called by muse, varscan2
- MKI67 | c.9625C>T p.P3209S | Missense Mutation (SNP) | VAF 72/205 reads (35%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.001); catalogued as COSV64073154; called by muse, mutect2, varscan2
- MKI67 | c.2708G>T p.C903F | Missense Mutation (SNP) | VAF 31/490 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV100897101; called by muse, mutect2
- MLF2 | c.412C>T p.R138W | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs745833590, COSV52570713; called by muse, mutect2, varscan2
- MMD | c.649G>A p.A217T | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.543); catalogued as COSV50434305; called by muse, mutect2, varscan2
- MMP13 | c.1225A>G p.N409D | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.07); catalogued as COSV52823291; called by muse, mutect2, varscan2
- MMP19 | c.376C>T p.R126W | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs201894718, COSV59450620; called by muse, mutect2, varscan2
- MMP20 | c.93del p.R32Gfs*37 | Frame Shift Del (DEL) | VAF 19/43 reads (44%) | catalogued as COSV99497522; called by mutect2, pindel, varscan2
- MMP8 | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV52631474; called by muse, mutect2, varscan2
- MON1B | c.1552C>T p.R518W | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs752840417, COSV50245617; called by muse, mutect2, varscan2
- MORN3 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs1398827320, COSV62507128; called by muse, mutect2, varscan2
- MPDZ | c.3874G>A p.A1292T | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as rs1329371374, COSV59916022; called by muse, mutect2, varscan2
- MRFAP1 | c.313A>G p.K105E | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as rs141440565; called by muse, mutect2, varscan2
- MRM3 | c.789G>A p.M263I | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV58679449; called by muse, mutect2, varscan2
- MRPS10 | c.244G>T p.G82C | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.376); catalogued as COSV50002457; called by muse, mutect2, varscan2
- MRTFB | c.2650del p.R884Afs*44 (on ENST00000571589 / NM_001365412.2; = p.R834Afs*44 on NM_014048.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 13/45 reads (29%) | catalogued as rs768684761; called by mutect2, pindel, varscan2
- MSRA | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.834); catalogued as COSV100412501; called by muse, varscan2
- MSTO1 | c.835C>T p.R279C | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); catalogued as rs761740567, COSV55471494; called by muse, mutect2, varscan2
- MTMR1 | c.1450C>T p.R484* | Nonsense Mutation (SNP) | VAF 26/130 reads (20%) | catalogued as COSV64892251; called by muse, mutect2, varscan2
- MTOR | c.5375C>T p.A1792V | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs868040471, COSV63868624, COSV63874757; called by muse, mutect2, varscan2
- MTRR | c.1757+2T>C p.X586_splice (on ENST00000264668; = p.X559_splice on NM_002454.3 and 4 other RefSeq transcripts) | Splice Site (SNP) | VAF 6/27 reads (22%) | catalogued as COSV99242231; called by muse, mutect2, varscan2
- MUC5B | c.7435G>A p.G2479R | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs760745894; called by mutect2, varscan2
- MUC5B | c.8657C>A p.P2886H | Missense Mutation (SNP) | VAF 45/152 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101500899, COSV71590536; called by muse, mutect2, varscan2
- MUC6 | c.3365G>T p.R1122M | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70136602; called by muse, mutect2, varscan2
- MVP | c.1795A>G p.I599V | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.669); catalogued as COSV100651791; called by muse, mutect2, varscan2
- MXRA5 | c.6527C>T p.P2176L | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs766618264, COSV54255614, COSV99477081; called by muse, mutect2, varscan2
- MYG1 | c.316G>A p.D106N | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99670568; called by muse, mutect2, varscan2
- MYH2 | c.3359G>A p.R1120H | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as rs752746936, COSV55433509; called by muse, mutect2, varscan2
- MYH2 | c.1417T>C p.F473L | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as COSV55433520; called by muse, mutect2, varscan2
- MYH7B | c.4274C>A p.A1425E | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as COSV52677824; called by muse, mutect2, varscan2
- MYH8 | c.1994T>C p.L665P | Missense Mutation (SNP) | VAF 46/165 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101239012; called by muse, mutect2, varscan2
- MYO18B | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.176); catalogued as rs1479705925, COSV59128407; called by muse, mutect2, varscan2
- MYO18B | c.5832A>C p.Q1944H | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV59128417; called by muse, mutect2, varscan2
- MYO1F | c.140T>C p.F47S | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100597205; called by muse, mutect2, varscan2
- MYO3B | c.1073C>T p.T358I | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.05); catalogued as COSV58697482; called by muse, mutect2, varscan2
- MYO5B | c.1201C>T p.R401C | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761492029, COSV53213429; called by muse, mutect2, varscan2
- MYO7B | c.3845G>A p.R1282H | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as rs201792059; called by muse, mutect2, varscan2
- MYOM3 | c.2357C>T p.S786L | Missense Mutation (SNP) | VAF 45/164 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as rs200850259; called by muse, mutect2, varscan2
- MYOM3 | c.709G>A p.G237S | Missense Mutation (SNP) | VAF 46/174 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267598456, COSV58391014; called by muse, mutect2, varscan2
- NBEA | c.3362del p.N1121Mfs*9 | Frame Shift Del (DEL) | VAF 9/45 reads (20%) | catalogued as rs763376147; called by mutect2, varscan2
- NBEAL2 | c.7181G>A p.R2394Q | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as rs779645523, COSV52756347; called by muse, mutect2, varscan2
- NBPF3 | c.68C>T p.P23L | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.022); catalogued as COSV59057482; called by muse, varscan2
- NCAPD3 | c.2725del p.Q909Rfs*10 | Frame Shift Del (DEL) | VAF 19/61 reads (31%) | catalogued as rs770284236; called by mutect2, pindel, varscan2
- NCKAP5 | c.3496G>A p.V1166M | Missense Mutation (SNP) | VAF 22/292 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs201602771, COSV58432948; called by muse, mutect2
- NCKAP5 | c.2315A>G p.K772R | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as COSV58432958; called by muse, mutect2, varscan2
- NCOA4 | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.054); catalogued as rs782570752; called by muse, mutect2, varscan2
- NCOA6 | c.3416A>G p.E1139G | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.297); catalogued as COSV62861963; called by muse, mutect2, varscan2
- NCOR1 | c.7172G>A p.R2391Q | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.652); catalogued as COSV51965339; called by muse, mutect2, varscan2
- NDUFA13 | c.415G>A p.G139S | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as rs1283817548, COSV53062858; called by muse, mutect2, varscan2
- NEBL | c.2534G>A p.R845H | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs761052528, COSV65802067, COSV65802342; called by muse, varscan2
- NEDD4 | c.2282T>G p.V761G (on ENST00000508342 / NM_001284338.1; = p.V342G on NM_006154.4) | Missense Mutation (SNP) | VAF 42/143 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV59059631, COSV59065748; called by muse, mutect2, varscan2
- NEGR1 | c.940+1G>A p.X314_splice | Splice Site (SNP) | VAF 5/48 reads (10%) | catalogued as COSV60833972; called by muse, mutect2
- NEIL3 | c.224G>A p.G75D | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV52809019; called by muse, varscan2
- NEURL4 | c.1612C>T p.R538C | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV59757174; called by muse, mutect2, varscan2
- NF1 | c.1625C>A p.A542D | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.448); catalogued as COSV62196225; called by muse, mutect2, varscan2
- NFATC1 | c.1331C>T p.T444M | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV53694378; called by muse, mutect2, varscan2
- NFATC1 | c.2069G>A p.R690H | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs779877080, COSV53696781; called by muse, mutect2, varscan2
- NFX1 | c.2926C>T p.R976C | Missense Mutation (SNP) | VAF 59/93 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as rs148050291; called by muse, mutect2, varscan2
- NIPBL | c.4856G>A p.R1619Q | Missense Mutation (SNP) | VAF 25/215 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as rs772077115, COSV56952388; called by muse, mutect2, varscan2
- NLGN4X | c.2299T>C p.S767P | Missense Mutation (SNP) | VAF 56/202 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.772); catalogued as COSV99324645; called by muse, mutect2, varscan2
- NLRP10 | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1484124969, COSV100150044; called by muse, mutect2, varscan2
- NLRP10 | c.292T>C p.Y98H | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as COSV60779154; called by muse, mutect2, varscan2
- NLRP11 | c.2191C>T p.R731* | Nonsense Mutation (SNP) | VAF 7/24 reads (29%) | catalogued as rs796621024, COSV100789840; called by muse, mutect2, varscan2
- NMUR2 | c.848C>T p.P283L | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369018357, COSV54916843; called by muse, mutect2, varscan2
- NOC4L | c.301A>G p.N101D | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV57957563; called by muse, mutect2
- NOC4L | c.612del p.A205Pfs*13 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | catalogued as rs1402340327; called by mutect2, pindel
- NOS1 | c.2027del p.G676Afs*64 | Frame Shift Del (DEL) | VAF 9/57 reads (16%) | catalogued as rs746543323; called by mutect2, pindel, varscan2
- NOS3 | c.1319del p.G440Afs*64 | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | catalogued as rs749517498, COSV52496454; called by mutect2, pindel, varscan2
- NOTCH1 | c.5837G>A p.R1946H | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs777423973, COSV53035995; ClinVar: uncertain significance; called by muse, mutect2, varscan2
1,222 further variants in this file (782 protein-altering or splice-affecting, 400 silent, 40 other) are not listed here.
